Somatic mutation profile of tumor specimen TCGA-EY-A215-01A (aliquot TCGA-EY-A215-01A-11D-A14K-09) from TCGA case TCGA-EY-A215, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G3; Age at diagnosis: 60.4 years (22,076 days).
Specimen TCGA-EY-A215-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6500310d-c698-4afd-9722-eb595c40bf29.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EY-A215-10A (Blood Derived Normal), aliquot TCGA-EY-A215-10A-01D-A14K-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/134864ea-696d-4d7c-bea3-eee7dd28d118

The open-access MAF lists 5,734 somatic variants for this specimen: 4,249 protein-altering or splice-affecting, 1,354 silent, 131 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3,598, Silent 1,354, Nonsense Mutation 236, Frame Shift Del 201, Splice Site 104, Frame Shift Ins 61, Intron 61, Splice Region 40, RNA 30, 3'UTR 18, 5'UTR 9, 5'Flank 7.

Variants (750 of 5,734; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC8 | c.3544C>T p.R1182W | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.629); catalogued as rs797045209, CM073983, COSV100216835; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACVRL1 | c.200G>A p.R67Q | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.037); catalogued as rs863223414, CM970042, COSV101187805, COSV66361103; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADGRV1 | c.2870dup p.N957Kfs*10 | Frame Shift Ins (INS) | VAF 17/50 reads (34%) | catalogued as rs397517429; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- AP1S1 | c.364del p.D122Mfs*11 | Frame Shift Del (DEL) | VAF 8/22 reads (36%) | catalogued as rs767358930; ClinVar: likely pathogenic; called by mutect2, varscan2
- CHD7 | c.5428C>T p.R1810* | Nonsense Mutation (SNP) | VAF 24/58 reads (41%) | catalogued as rs1554603552, CM060223, COSV71114014; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CHD8 | c.6649C>T p.R2217* (on ENST00000646647 / NM_001170629.2; = p.R1938* on NM_020920.4) | Nonsense Mutation (SNP) | VAF 31/63 reads (49%) | catalogued as rs1555313048, COSV63037178; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DSG4 | c.865C>T p.R289* | Nonsense Mutation (SNP) | VAF 18/46 reads (39%) | catalogued as rs267606777, CM061705, COSV57389289; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DSP | c.2131_2132del p.X711_splice | Splice Site (DEL) | VAF 12/34 reads (35%) | catalogued as rs587782927; ClinVar: likely pathogenic / pathogenic; called by pindel, varscan2
- EP300 | c.4585C>T p.R1529* | Nonsense Mutation (SNP) | VAF 18/28 reads (64%) | catalogued as rs1569118537, CM162047, COSV54325565; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FOXP1 | c.1573C>T p.R525* | Nonsense Mutation (SNP) | VAF 37/84 reads (44%) | catalogued as rs112795301, CM107720, COSV59537299; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FUS | c.1562G>A p.R521H | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs121909671, CM091091, CM104703, COSV99568433; ClinVar: pathogenic; called by muse, mutect2, varscan2
- IARS1 | c.2215C>T p.R739C | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747311061, COSV65115733; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KCNMA1 | c.2026del p.Y676Tfs*15 | Frame Shift Del (DEL) | VAF 5/26 reads (19%) | catalogued as rs762705295; ClinVar: pathogenic; called by pindel, varscan2
- LARP7 | c.1213del p.T405Qfs*5 | Frame Shift Del (DEL) | VAF 8/18 reads (44%) | catalogued as rs750946801; ClinVar: likely pathogenic; called by mutect2, varscan2
- LDLR | c.811G>A p.V271I | Missense Mutation (SNP) | VAF 37/77 reads (48%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs749220643, CM160466, COSV52944518; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- MED23 | c.3982C>T p.R1328C | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs766478634, COSV51580995; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- MFRP | c.3del p.H2Tfs*100 (on ENST00000449574; = p.H384Tfs*94 on NM_031433.4) | Frame Shift Del (DEL) | VAF 12/33 reads (36%) | catalogued as rs587776595; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- MLH1 | c.380G>T p.R127I | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs63751595, CM151998, CM158549, CS066295, COSV51614450, COSV99212360; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- MSH2 | c.687dup p.A230Sfs*2 | Frame Shift Ins (INS) | VAF 8/27 reads (30%) | catalogued as rs63749897; ClinVar: pathogenic; called by mutect2, varscan2
- MSH6 | c.3261del p.F1088Sfs*2 | Frame Shift Del (DEL) | VAF 8/22 reads (36%) | hotspot (GDC flag); catalogued as rs267608078, COSV99029757; ClinVar: pathogenic; called by mutect2, varscan2
- MTM1 | c.969del p.V324* | Frame Shift Del (DEL) | VAF 19/49 reads (39%) | catalogued as rs587783865; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- MYH7 | c.2711G>A p.R904H | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs397516165, CM115866, COSV100805835; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- NEFL | c.446C>T p.A149V | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.835); catalogued as rs59101996, CM024133, COSV55338106; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- NR5A1 | c.938G>A p.R313H | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1554721235, CM127614, COSV101007652; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTEN | c.605C>T p.T202I | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs1085308053, CM090866, COSV100909744; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SAMHD1 | c.427C>T p.R143C | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs387906948, CM093965, COSV99483885; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SLC26A2 | c.438del p.F146Lfs*26 | Frame Shift Del (DEL) | VAF 37/102 reads (36%) | catalogued as rs769859976; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- SMARCB1 | c.982C>T p.R328W (on ENST00000263121; = p.R374W on NM_003073.5) | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs1568963596, COSV51954374, COSV51955307; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SMARCE1 | c.751C>T p.R251* | Nonsense Mutation (SNP) | VAF 21/43 reads (49%) | catalogued as rs1057518166, COSV99228311; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SMPD1 | c.1492C>T p.R498C | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs769904764, CM023161, COSV100192498; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- A1CF | c.1580A>G p.D527G (on ENST00000373993 / NM_138932.2; = p.D519G on NM_014576.4) | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.02); catalogued as COSV99255539; called by muse, mutect2, varscan2
- A2M | c.667G>A p.E223K | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100588533; called by muse, mutect2, varscan2
- A2ML1 | c.1801C>T p.L601F | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV100228647; called by muse, mutect2, varscan2
- AADACL2 | c.317C>T p.A106V | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100735625, COSV62929925; called by muse, mutect2, varscan2
- AARS2 | c.2685G>A p.V895= | Splice Region (SNP) | VAF 26/43 reads (60%) | catalogued as COSV99771312; called by muse, mutect2, varscan2
- AASS | c.655T>C p.F219L | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); catalogued as COSV100741726; called by muse, mutect2, varscan2
- ABCA12 | c.1956+2C>T p.X652_splice (on ENST00000272895 / NM_173076.3; = p.X334_splice on NM_015657.3) | Splice Site (SNP) | VAF 12/26 reads (46%) | catalogued as COSV55953026, COSV99788960; called by muse, mutect2, varscan2
- ABCA13 | c.2921A>G p.E974G | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.295); catalogued as rs1037090857, COSV101329965; called by muse, mutect2, varscan2
- ABCA13 | c.9811G>T p.E3271* | Nonsense Mutation (SNP) | VAF 4/10 reads (40%) | catalogued as COSV101446869; called by muse, mutect2, varscan2
- ABCA2 | c.3662G>A p.R1221H (on ENST00000614293; = p.R1191H on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 49/112 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99687162; called by muse, mutect2, varscan2
- ABCA2 | c.3004C>T p.R1002W (on ENST00000614293; = p.R972W on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs748428134, COSV99687163; called by muse, mutect2, varscan2
- ABCA2 | c.2641G>A p.A881T (on ENST00000614293; = p.A851T on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1396280548, COSV99687164; called by muse, mutect2, varscan2
- ABCA3 | c.3731C>T p.T1244I | Missense Mutation (SNP) | VAF 47/95 reads (49%) | SIFT tolerated (0.31); PolyPhen benign (0.017); catalogued as rs1276722634, COSV57052908; called by muse, mutect2, varscan2
- ABCA7 | c.5560G>A p.A1854T | Missense Mutation (SNP) | VAF 33/85 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.194); catalogued as COSV99565363; called by muse, mutect2, varscan2
- ABCB11 | c.3562G>A p.V1188I | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.036); catalogued as COSV99791730; called by mutect2, varscan2
- ABCB11 | c.3049G>A p.V1017M | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.998); catalogued as COSV99791732; called by muse, mutect2, varscan2
- ABCB4 | c.2175G>T p.Q725H | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.988); catalogued as COSV99709930; called by muse, mutect2, varscan2
- ABCB5 | c.1360G>A p.A454T (on ENST00000404938 / NM_001163941.2; = p.A9T on NM_178559.6) | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV99327778; called by muse, mutect2, varscan2
- ABCC1 | c.3717G>T p.Q1239H | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748378518, COSV100578935; called by muse, mutect2, varscan2
- ABCC11 | c.4088G>A p.R1363Q | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs1185647784, COSV100750612; called by muse, mutect2, varscan2
- ABCC11 | c.1680G>A p.E560= | Splice Region (SNP) | VAF 15/39 reads (38%) | catalogued as rs1227080279, COSV100750614; called by muse, mutect2, varscan2
- ABCC4 | c.2929G>A p.G977R | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs970160658, COSV100972349; called by muse, mutect2, varscan2
- ABCC5 | c.3010G>A p.V1004M | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.358); catalogued as rs1422352993, COSV99656599; called by muse, mutect2, varscan2
- ABCC5 | c.2350C>A p.L784M | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.017); catalogued as COSV99656601; called by muse, mutect2, varscan2
- ABCC9 | c.2119G>A p.V707I | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.883); catalogued as COSV99684961; called by muse, mutect2, varscan2
- ABCE1 | c.568C>T p.R190* | Nonsense Mutation (SNP) | VAF 10/28 reads (36%) | catalogued as COSV99668463; called by muse, mutect2, varscan2
- ABCG1 | c.1516G>A p.D506N | Missense Mutation (SNP) | VAF 31/97 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100493926; called by muse, mutect2, varscan2
- ABCG2 | c.203+2T>C p.X68_splice | Splice Site (SNP) | VAF 24/48 reads (50%) | catalogued as rs1282888435, COSV99418724; called by muse, mutect2, varscan2
- ABCG8 | c.34C>T p.P12S | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0); catalogued as COSV53212535; called by muse, mutect2
- ABHD6 | c.4G>A p.D2N | Missense Mutation (SNP) | VAF 46/101 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.82); catalogued as COSV99916948; called by muse, mutect2, varscan2
- ABLIM1 | c.1961C>T p.A654V | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.236); catalogued as rs1002965728, COSV99521703; called by muse, mutect2, varscan2
- ABLIM1 | c.1796G>A p.R599H | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.869); catalogued as rs754281771, COSV53306078; called by muse, mutect2, varscan2
- ABLIM1 | c.313C>T p.P105S | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0.229); catalogued as COSV99521707; called by muse, mutect2, varscan2
- ABRA | c.1118A>T p.D373V | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100357499; called by muse, mutect2, varscan2
- ABRAXAS1 | c.754C>T p.R252* | Nonsense Mutation (SNP) | VAF 10/22 reads (45%) | catalogued as rs1300270870, COSV55029469; called by muse, mutect2, varscan2
- AC011448.1 | c.499G>A p.E167K | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.93); catalogued as rs367672641; called by muse, mutect2, varscan2
- AC011455.2 | c.1763G>A p.S588N | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.044); catalogued as COSV99671182; called by muse, mutect2, varscan2
- AC013489.1 | c.1598A>G p.Q533R | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99183838; called by muse, mutect2, varscan2
- AC018630.4 | c.205C>T p.P69S | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.947); catalogued as COSV99958497; called by muse, mutect2, varscan2
- AC068580.4 | c.511G>A p.G171S | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.325); catalogued as rs775460488, COSV52587726; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AC090517.4 | c.1053C>A p.Y351* | Nonsense Mutation (SNP) | VAF 46/100 reads (46%) | catalogued as COSV99974199; called by muse, mutect2, varscan2
- AC126283.2 | c.1060C>T p.Q354* | Nonsense Mutation (SNP) | VAF 18/40 reads (45%) | catalogued as CM086398, COSV101144215; called by muse, mutect2, varscan2
- ACACB | c.2845G>T p.G949C | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100622532; called by muse, mutect2, varscan2
- ACACB | c.7057G>A p.V2353M | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs764524027, COSV100622536; called by muse, mutect2, varscan2
- ACCS | c.1151G>A p.R384Q | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as rs533274352, COSV99772727; called by muse, mutect2, varscan2
- ACE | c.1937A>G p.E646G | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99326603; called by mutect2, varscan2
- ACHE | c.1186G>A p.V396I | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as COSV99573861; called by muse, mutect2, varscan2
- ACHE | c.145C>T p.R49W | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1428177392, COSV53818193; called by muse, mutect2, varscan2
- ACKR3 | c.749G>A p.S250N | Missense Mutation (SNP) | VAF 33/59 reads (56%) | SIFT tolerated (0.16); PolyPhen benign (0.028); catalogued as COSV99799408; called by muse, mutect2, varscan2
- ACLY | c.668C>G p.A223G | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated (0.16); PolyPhen benign (0.077); catalogued as COSV100709549, COSV100709574; called by muse, mutect2, varscan2
- ACOT12 | c.1322C>A p.P441H | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV100296804, COSV100296910; called by muse, mutect2, varscan2
- ACOX3 | c.866C>T p.P289L | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.197); catalogued as COSV100711859; called by muse, mutect2, varscan2
- ACOXL | c.754C>A p.L252I | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0.055); catalogued as COSV100489986; called by muse, mutect2, varscan2
- ACRBP | c.1099C>T p.R367* | Nonsense Mutation (SNP) | VAF 22/59 reads (37%) | catalogued as rs764217842, COSV99976002; called by muse, mutect2, varscan2
- ACRBP | c.506C>A p.P169H | Missense Mutation (SNP) | VAF 41/111 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV99976005; called by muse, mutect2, varscan2
- ACSBG1 | c.1300G>A p.A434T | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT tolerated (0.3); PolyPhen benign (0.065); catalogued as COSV99357149; called by muse, mutect2, varscan2
- ACSF3 | c.617C>T p.T206M | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs142038371, COSV100441159; called by muse, mutect2, varscan2
- ACSL1 | c.692G>A p.G231D | Missense Mutation (SNP) | VAF 42/85 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs569889960, COSV99860449; called by muse, mutect2, varscan2
- ACSL1 | c.133G>A p.A45T | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.23); PolyPhen benign (0.014); catalogued as rs1195128727, COSV55662092, COSV99860452; called by muse, mutect2, varscan2
- ACSL1 | c.23G>A p.R8Q | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.006); catalogued as rs201421906, COSV99860454; called by muse, mutect2, varscan2
- ACSM3 | c.32G>A p.R11H | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.001); catalogued as rs756159393, COSV99184047; called by muse, mutect2, varscan2
- ACSM5 | c.361G>T p.V121L | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.022); catalogued as COSV100088586; called by muse, mutect2, varscan2
- ACTA2 | c.607G>A p.V203I | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.015); catalogued as rs397516684, CM145697, COSV56515587; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ACTB | c.1003C>T p.R335C | Missense Mutation (SNP) | VAF 59/151 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.204); catalogued as COSV59319915; called by muse, mutect2, varscan2
- ACTB | c.172G>A p.A58T | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100079475; called by muse, mutect2, varscan2
- ACTL9 | c.982C>A p.L328M | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.605); catalogued as COSV61005075, COSV61007595; called by muse, mutect2, varscan2
- ACTR5 | c.375G>A p.Q125= | Splice Region (SNP) | VAF 6/33 reads (18%) | catalogued as COSV54761460, COSV54762715; called by muse, mutect2, varscan2
- ACTRT1 | c.629C>T p.A210V | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.334); catalogued as COSV64420239; called by muse, mutect2, varscan2
- ACVR1B | c.1208T>C p.I403T | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99231321; called by muse, mutect2, varscan2
- ACVR2A | c.1031C>T p.A344V | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54028380, COSV99604162; called by muse, mutect2, varscan2
- ACY3 | c.346C>T p.H116Y | Missense Mutation (SNP) | VAF 31/61 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99662919; called by muse, mutect2, varscan2
- ADAM19 | c.1309-1G>A p.X437_splice | Splice Site (SNP) | VAF 14/27 reads (52%) | catalogued as COSV57435662, COSV99976513; called by muse, mutect2, varscan2
- ADAM2 | c.746C>T p.T249I | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs752643285, COSV55859510; called by muse, mutect2, varscan2
- ADAM2 | c.482G>T p.R161I | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as COSV99696974; called by muse, mutect2, varscan2
- ADAM29 | c.1798G>T p.D600Y | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63664722; called by muse, mutect2, varscan2
- ADAM9 | c.2066A>C p.N689T | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.864); catalogued as COSV101166041; called by muse, mutect2, varscan2
- ADAMTS10 | c.3258C>A p.F1086L | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.805); catalogued as COSV99546607; called by muse, mutect2, varscan2
- ADAMTS15 | c.1081C>T p.H361Y | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100143193; called by muse, mutect2, varscan2
- ADAMTS16 | c.716G>A p.R239H | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs747859566, COSV57005038; called by muse, mutect2, varscan2
- ADAMTS16 | c.1208-1G>T p.X403_splice | Splice Site (SNP) | VAF 17/43 reads (40%) | catalogued as COSV57006561; called by muse, mutect2, varscan2
- ADAMTS19 | c.1925C>T p.A642V | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.094); catalogued as COSV99176623; called by muse, mutect2, varscan2
- ADAMTS2 | c.2033C>T p.T678M | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs780713793, COSV99281346; called by muse, mutect2
- ADAMTS7 | c.1302G>T p.Q434H | Missense Mutation (SNP) | VAF 37/89 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); catalogued as COSV101183052; called by muse, mutect2, varscan2
- ADAMTSL1 | c.544G>T p.G182W | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52825927; called by muse, mutect2, varscan2
- ADAMTSL1 | c.2752C>A p.L918I | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.614); catalogued as COSV101001494; called by muse, mutect2, varscan2
- ADAMTSL1 | c.4215G>T p.Q1405H | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.477); catalogued as COSV101000430; called by muse, mutect2
- ADAMTSL1 | c.5264G>A p.C1755Y | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101000836; called by muse, mutect2, varscan2
- ADCY1 | c.757C>T p.R253* | Nonsense Mutation (SNP) | VAF 59/131 reads (45%) | catalogued as COSV52041053; called by muse, mutect2, varscan2
- ADCY1 | c.2173G>A p.E725K | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs1238664795, COSV99811531; called by muse, mutect2, varscan2
- ADCY10 | c.560T>C p.V187A | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as COSV100896668; called by muse, mutect2, varscan2
- ADCY2 | c.2557C>A p.R853S | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV57896656; called by muse, mutect2, varscan2
- ADCY4 | c.1935G>A p.M645I | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV100156297, COSV60255321; called by muse, mutect2, varscan2
- ADCY5 | c.997G>A p.V333M | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.062); catalogued as rs781458896, COSV101518400, COSV71901891; called by muse, mutect2, varscan2
- ADCY6 | c.3083A>C p.E1028A | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100326496, COSV57170408; called by muse, mutect2, varscan2
- ADCY7 | c.2960G>A p.R987H | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs757612325, COSV54265462; called by muse, mutect2, varscan2
- ADCY9 | c.250G>A p.E84K | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.03); catalogued as COSV53582760; called by muse, mutect2, varscan2
- ADCYAP1 | c.278G>A p.R93H | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs760235350, COSV52486433; called by muse, varscan2
- ADCYAP1R1 | c.719A>G p.N240S | Missense Mutation (SNP) | VAF 70/151 reads (46%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.992); catalogued as COSV100416311; called by muse, mutect2, varscan2
- ADD2 | c.2035A>G p.T679A | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100034987; called by muse, mutect2, varscan2
- ADGRA2 | c.596G>A p.R199H | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs773004412, COSV100177617, COSV100177671; called by muse, mutect2, varscan2
- ADGRA3 | c.1283A>C p.N428T | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.815); catalogued as COSV99293057; called by muse, mutect2
- ADGRB3 | c.122C>T p.S41L | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.69); PolyPhen probably damaging (0.921); catalogued as rs745590202, COSV65385300; called by muse, mutect2, varscan2
- ADGRF1 | c.1849del p.S617Afs*12 | Frame Shift Del (DEL) | VAF 31/67 reads (46%) | catalogued as rs1344904964; called by mutect2, pindel, varscan2
- ADGRF4 | c.506del p.N169Ifs*15 | Frame Shift Del (DEL) | VAF 10/34 reads (29%) | catalogued as rs1178459999; called by mutect2, pindel, varscan2
- ADGRF5 | c.3819A>G p.V1273= | Splice Region (SNP) | VAF 9/23 reads (39%) | catalogued as rs754995009, COSV99345150; called by muse, mutect2, varscan2
- ADGRG2 | c.1180G>A p.E394K (on ENST00000379869 / NM_001079858.3; = p.E391K on NM_005756.4) | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.771); catalogued as COSV100492040; called by muse, mutect2, varscan2
- ADGRG4 | c.108dup p.G37Wfs*4 | Frame Shift Ins (INS) | VAF 23/64 reads (36%) | catalogued as rs1238901032; called by mutect2, varscan2
- ADGRG4 | c.9223C>T p.P3075S | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0.062); catalogued as COSV99794813; called by muse, mutect2, varscan2
- ADGRG7 | c.1232G>A p.R411H | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as rs763246023, COSV56298481, COSV99841298; called by muse, mutect2, varscan2
- ADGRL1 | c.1306C>T p.R436W (on ENST00000340736 / NM_001008701.3; = p.R431W on NM_014921.5) | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs752482599, COSV100529346; called by muse, mutect2, varscan2
- ADGRL4 | c.1985del p.L662Yfs*28 | Frame Shift Del (DEL) | VAF 11/30 reads (37%) | catalogued as rs770040543; called by mutect2, pindel, varscan2
- ADGRV1 | c.12554G>A p.G4185E | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as CM1310595, COSV101315634, COSV101316486; called by muse, mutect2, varscan2
- ADNP2 | c.386C>T p.A129V | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.053); catalogued as rs749501244, COSV100080628; called by muse, mutect2, varscan2
- ADORA2B | c.671C>T p.T224I | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.221); catalogued as rs80241126, COSV100419983; called by muse, varscan2
- ADORA2B | c.710C>T p.A237V | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.373); catalogued as COSV100419984; called by muse, varscan2
- ADPRM | c.404T>C p.I135T | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT tolerated (0.75); PolyPhen possibly damaging (0.571); catalogued as rs762091779, COSV101126061; called by muse, mutect2, varscan2
- ADRA2A | c.1175C>T p.A392V | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs771143397, COSV54528591; called by muse, mutect2, varscan2
- ADTRP | c.593C>T p.S198F | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT tolerated (0.75); PolyPhen benign (0.005); catalogued as COSV57641601, COSV99995114; called by muse, mutect2, varscan2
- AFF2 | c.263A>G p.H88R | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.64); PolyPhen possibly damaging (0.847); catalogued as rs782381902, COSV100649418; called by muse, mutect2, varscan2
- AFF2 | c.2948C>T p.T983I | Missense Mutation (SNP) | VAF 32/95 reads (34%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as COSV99662619; called by muse, mutect2, varscan2
- AFF3 | c.2843C>T p.P948L | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT tolerated (0.37); PolyPhen benign (0.005); catalogued as rs1347906445, COSV100418230; called by muse, mutect2, varscan2
- AFF3 | c.1354dup p.H452Pfs*8 | Frame Shift Ins (INS) | VAF 16/42 reads (38%) | catalogued as rs759949420; called by mutect2, varscan2
- AFG3L2 | c.1857G>T p.E619D | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.539); catalogued as COSV99301646; called by muse, mutect2, varscan2
- AFP | c.592G>A p.A198T | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.795); catalogued as COSV99889827; called by muse, mutect2, varscan2
- AFP | c.1240C>T p.R414* | Nonsense Mutation (SNP) | VAF 6/25 reads (24%) | catalogued as rs374322791; called by muse, mutect2, varscan2
- AGBL4 | c.1123C>T p.R375W | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs753216988, COSV61893285; called by muse, varscan2
- AGER | c.694C>T p.P232S | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.043); catalogued as rs1366680556, COSV100426127; called by muse, mutect2, varscan2
- AGMO | c.245C>T p.S82F | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.347); catalogued as COSV100693823; called by muse, mutect2, varscan2
- AGO1 | c.1601G>A p.G534E | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV100940780; called by muse, mutect2, varscan2
- AGPAT1 | c.574C>T p.R192C | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.985); catalogued as rs1349120316, COSV61248802; called by muse, mutect2, varscan2
- AGPAT1 | c.451C>T p.R151C | Missense Mutation (SNP) | VAF 13/21 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs1236603443, COSV61247029; called by muse, mutect2, varscan2
- AGPAT1 | c.259C>T p.R87* | Nonsense Mutation (SNP) | VAF 21/51 reads (41%) | catalogued as COSV61246915, COSV61248990; called by muse, mutect2, varscan2
- AGTRAP | c.280C>A p.L94I | Missense Mutation (SNP) | VAF 67/156 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.37); catalogued as COSV100065221; called by muse, mutect2, varscan2
- AHI1 | c.1333C>A p.L445M | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99662220; called by muse, mutect2, varscan2
- AHNAK | c.13900G>T p.V4634L | Missense Mutation (SNP) | VAF 61/122 reads (50%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.981); catalogued as COSV99946275; called by muse, mutect2, varscan2
- AHNAK2 | c.13382G>T p.S4461I | Missense Mutation (SNP) | VAF 64/152 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as COSV100316359; called by muse, mutect2, varscan2
- AHSG | c.170A>T p.K57I | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99889906; called by muse, mutect2, varscan2
- AJAP1 | c.1228T>A p.S410T | Missense Mutation (SNP) | VAF 41/96 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100981544; called by muse, mutect2, varscan2
- AJUBA | c.1273G>T p.G425C | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99400872; called by muse, mutect2, varscan2
- AK4 | c.249G>T p.Q83H | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV100519811; called by muse, mutect2, varscan2
- AK9 | c.158C>T p.A53V | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.559); catalogued as rs1339890107, COSV99572413; called by muse, mutect2, varscan2
- AKAP12 | c.484C>T p.P162S | Missense Mutation (SNP) | VAF 22/41 reads (54%) | SIFT tolerated (0.08); PolyPhen benign (0.011); catalogued as COSV99482765; called by muse, mutect2, varscan2
- AKAP13 | c.5724G>T p.Q1908H (on ENST00000394518 / NM_007200.5; = p.Q1912H on NM_006738.6) | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.38); catalogued as rs1368388385, COSV100773315, COSV63448948; called by muse, mutect2, varscan2
- AKAP4 | c.1825C>T p.P609S | Missense Mutation (SNP) | VAF 35/74 reads (47%) | SIFT tolerated (0.39); PolyPhen benign (0.018); catalogued as COSV100654200; called by muse, mutect2, varscan2
- AKAP9 | c.3005A>T p.N1002I | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.351); catalogued as COSV100662108; called by mutect2, varscan2
- AKIRIN2 | c.461G>A p.R154H | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as COSV100005184; called by muse, mutect2, varscan2
- AKR1C4 | c.106G>A p.E36K | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.158); catalogued as COSV99578558; called by muse, mutect2, varscan2
- AKR1D1 | c.232C>T p.R78W | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.769); catalogued as rs368152787, COSV54338420; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AKR1D1 | c.720G>T p.K240N | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV99652895; called by muse, mutect2, varscan2
- AKT3 | c.922G>T p.G308C | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99794572; called by muse, mutect2, varscan2
- AL121899.2 | c.1463C>T p.T488M | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.062); catalogued as rs771056380, COSV67352063; called by muse, mutect2, varscan2
- AL136295.1 | c.2439G>T p.K813N | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99937862; called by muse, mutect2, varscan2
- AL162417.1 | c.335C>A p.S112Y | Missense Mutation (SNP) | VAF 45/108 reads (42%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.461); catalogued as COSV100923123; called by muse, mutect2, varscan2
- ALAS2 | c.1084G>A p.V362I | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.912); catalogued as COSV100238099; called by muse, mutect2, varscan2
- ALDH16A1 | c.1699C>T p.R567* | Nonsense Mutation (SNP) | VAF 30/68 reads (44%) | catalogued as rs777019923, COSV99512688; called by muse, mutect2, varscan2
- ALDH1A1 | c.311C>T p.A104V | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.712); catalogued as rs927636872, COSV52790587; called by muse, mutect2, varscan2
- ALDH1A3 | c.1493C>T p.T498I | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); catalogued as rs1168265416, COSV99438302; called by muse, mutect2, varscan2
- ALDH4A1 | c.329T>C p.L110P | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as COSV99311650; called by muse, mutect2, varscan2
- ALDH7A1 | c.386G>T p.G129V | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101297444; called by muse, mutect2, varscan2
- ALDOB | c.128G>A p.R43H | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as rs780442649, COSV66398306; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALG10 | c.482T>G p.L161R | Missense Mutation (SNP) | VAF 36/79 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99847982; called by muse, mutect2, varscan2
- ALG14 | c.640C>T p.R214* | Nonsense Mutation (SNP) | VAF 10/26 reads (38%) | catalogued as rs750095172, COSV100930835, COSV64635505; called by muse, mutect2
- ALKBH5 | c.1174C>T p.R392W | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs765718566, COSV101213354, COSV67687134; called by muse, mutect2, varscan2
- ALMS1 | c.11769T>G p.S3923R | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV100041627; called by muse, varscan2
- ALOXE3 | c.935C>T p.T312I | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100559648; called by muse, mutect2, varscan2
- ALPI | c.946C>T p.R316C | Missense Mutation (SNP) | VAF 67/136 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.075); catalogued as rs148557980; called by muse, mutect2, varscan2
- ALPK2 | c.5539C>T p.Q1847* | Nonsense Mutation (SNP) | VAF 16/38 reads (42%) | catalogued as rs80273727, COSV100864197; called by muse, mutect2, varscan2
- ALPK2 | c.2234A>C p.E745A | Missense Mutation (SNP) | VAF 49/93 reads (53%) | SIFT tolerated (0.06); PolyPhen benign (0.118); catalogued as COSV100864199; called by muse, mutect2, varscan2
- ALPK2 | c.1489A>C p.K497Q | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.074); catalogued as COSV100864200, COSV100864941; called by muse, mutect2, varscan2
- ALPK3 | c.559C>T p.R187C | Missense Mutation (SNP) | VAF 21/35 reads (60%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.791); catalogued as COSV99360476; called by muse, mutect2, varscan2
- ALPP | c.1586T>C p.L529P | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.795); catalogued as COSV101235119; called by muse, varscan2
- ALS2 | c.4125C>A p.A1375= | Splice Region (SNP) | VAF 5/17 reads (29%) | catalogued as COSV51883902; called by muse, mutect2, varscan2
- ALX4 | c.376C>T p.R126* | Nonsense Mutation (SNP) | VAF 8/22 reads (36%) | catalogued as COSV100240953; called by muse, varscan2
- AMBRA1 | c.2831C>T p.A944V (on ENST00000458649 / NM_001367468.1; = p.A854V on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/56 reads (52%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.985); catalogued as COSV100093156; called by muse, mutect2, varscan2
- AMMECR1 | c.892C>T p.R298C | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.234); catalogued as COSV99466445; called by muse, mutect2, varscan2
- AMPD2 | c.185G>A p.R62H | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.98); catalogued as rs749976113, COSV99857477; called by muse, mutect2, varscan2
- AMPD3 | c.277C>T p.Q93* (on ENST00000396553 / NM_001025389.2; = p.Q102* on NM_000480.3) | Nonsense Mutation (SNP) | VAF 8/44 reads (18%) | catalogued as COSV101158114; called by muse, mutect2, varscan2
- AMPD3 | c.809C>T p.T270M (on ENST00000396553 / NM_001025389.2; = p.T279M on NM_000480.3) | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.879); catalogued as rs754844590, COSV101158115; called by muse, mutect2, varscan2
- AMPD3 | c.2290G>A p.A764T (on ENST00000396553 / NM_001025389.2; = p.A773T on NM_000480.3) | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as rs767689124, COSV101158116, COSV67332747; called by muse, mutect2, varscan2
- AMPH | c.1993C>A p.L665M | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV100341367; called by muse, mutect2, varscan2
- AMPH | c.1733C>T p.T578I | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT tolerated (0.16); PolyPhen benign (0.157); catalogued as COSV100341369; called by muse, mutect2
- AMY2B | c.323T>G p.I108S | Missense Mutation (SNP) | VAF 57/142 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); catalogued as COSV100796229; called by muse, mutect2, varscan2
- AMZ2 | c.205G>T p.D69Y | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100703125, COSV63083288; called by muse, mutect2, varscan2
- ANAPC2 | c.2113C>A p.L705M | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100118952; called by muse, mutect2, varscan2
- ANAPC2 | c.1018C>T p.R340C | Missense Mutation (SNP) | VAF 44/95 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV59245457; called by muse, mutect2, varscan2
- ANAPC2 | c.500G>T p.R167I | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV100118954, COSV58808783; called by muse, mutect2, varscan2
- ANAPC2 | c.302C>A p.S101Y | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV100118955; called by muse, mutect2, varscan2
- ANAPC4 | c.742G>A p.V248I | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.084); catalogued as COSV100193890; called by muse, mutect2, varscan2
- ANAPC7 | c.197A>G p.N66S | Missense Mutation (SNP) | VAF 32/60 reads (53%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.568); catalogued as COSV101484776; called by muse, mutect2, varscan2
- ANGPT2 | c.1213G>T p.G405* | Nonsense Mutation (SNP) | VAF 18/54 reads (33%) | catalogued as COSV100290757; called by muse, mutect2, varscan2
- ANGPT2 | c.700del p.I234* | Frame Shift Del (DEL) | VAF 14/40 reads (35%) | catalogued as rs34047276; called by mutect2, varscan2
- ANGPT4 | c.1474C>T p.R492C | Missense Mutation (SNP) | VAF 52/120 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1365799158, COSV67921336; called by muse, mutect2, varscan2
- ANGPTL2 | c.1196G>A p.R399H | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT tolerated (0.35); PolyPhen benign (0.168); catalogued as rs764497308, COSV52216437; called by muse, mutect2, varscan2
- ANK1 | c.2340T>G p.I780M | Missense Mutation (SNP) | VAF 27/49 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV99224462; called by muse, mutect2, varscan2
- ANK2 | c.586C>A p.L196M | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100000385; called by muse, mutect2, varscan2
- ANK2 | c.3380-1G>A p.X1127_splice | Splice Site (SNP) | VAF 11/29 reads (38%) | catalogued as COSV100000388; called by muse, mutect2, varscan2
- ANKAR | c.3653T>C p.L1218S | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99854008; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.247G>A p.V83M | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.981); catalogued as COSV99782527; called by muse, mutect2
- ANKIB1 | c.2170T>G p.F724V | Missense Mutation (SNP) | VAF 13/19 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs886394741, COSV56059664, COSV99728628; called by muse, mutect2, varscan2
- ANKK1 | c.1339C>T p.L447F | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1162862147, COSV100392739; called by muse, mutect2
- ANKRD11 | c.7094C>T p.P2365L | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); catalogued as rs1258300974, COSV99968646; called by muse, mutect2, varscan2
- ANKRD13C | c.482A>G p.H161R | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT tolerated (0.96); PolyPhen benign (0.01); catalogued as COSV99256442; called by muse, mutect2, varscan2
- ANKRD20A1 | c.518C>A p.A173D | Missense Mutation (SNP) | VAF 16/165 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs202214101; called by muse, mutect2, varscan2
- ANKRD20A4P | c.1171A>G p.T391A | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT tolerated (0.34); PolyPhen benign (0.013); catalogued as COSV100628449; called by muse, mutect2, varscan2
- ANKRD23 | c.397G>A p.D133N | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100450367; called by muse, mutect2, varscan2
- ANKRD26 | c.3823G>A p.D1275N | Missense Mutation (SNP) | VAF 11/17 reads (65%) | SIFT tolerated (0.15); PolyPhen benign (0.023); catalogued as COSV101063014; called by muse, mutect2, varscan2
- ANKRD27 | c.1427C>T p.A476V | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.111); catalogued as COSV100042638; called by muse, mutect2, varscan2
- ANKRD35 | c.656G>A p.G219E | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62910879; called by muse, mutect2, varscan2
- ANKRD44 | c.2816del p.N939Ifs*16 | Frame Shift Del (DEL) | VAF 12/37 reads (32%) | catalogued as rs1408961377; called by mutect2, pindel, varscan2
- ANKRD50 | c.1639A>C p.T547P | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV101538908; called by muse, mutect2, varscan2
- ANKRD52 | c.403G>A p.V135M | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.378); catalogued as rs368473098, COSV99921136; called by muse, mutect2, varscan2
- ANKRD55 | c.1759C>A p.L587I | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.883); catalogued as COSV100591156; called by muse, mutect2, varscan2
- ANKRD9 | c.880C>T p.R294C | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV99743559; called by muse, varscan2
- ANKZF1 | c.68C>T p.A23V | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT tolerated (0.18); PolyPhen benign (0.018); catalogued as COSV100036823; called by muse, mutect2, varscan2
- ANO9 | c.811G>A p.A271T | Missense Mutation (SNP) | VAF 30/57 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766520769, COSV100240810; called by muse, mutect2, varscan2
- ANXA1 | c.145G>A p.A49T | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.033); catalogued as rs142511024; called by muse, mutect2, varscan2
- AOC3 | c.2099G>A p.G700D | Missense Mutation (SNP) | VAF 37/106 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.738); catalogued as COSV100395975; called by muse, mutect2, varscan2
- AOX1 | c.1631G>A p.S544N | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as COSV101021828; called by muse, mutect2, varscan2
- AP002748.5 | c.1702C>T p.P568S | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.54); PolyPhen benign (0.137); catalogued as rs535565890, COSV100567774; called by muse, mutect2, varscan2
- AP1G1 | c.2228T>C p.L743P | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.35); PolyPhen benign (0.232); catalogued as COSV100250187; called by muse, mutect2, varscan2
- AP1S2 | c.443G>A p.R148H | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.238); catalogued as COSV57063747; called by muse, mutect2, varscan2
- AP4B1 | c.1871G>A p.R624H | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs750402059, COSV99870648; called by muse, mutect2, varscan2
- AP5Z1 | c.968C>A p.A323D | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100804039; called by muse, mutect2, varscan2
- APBA3 | c.769G>A p.D257N | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.599); catalogued as rs890201932, COSV53662635; called by muse, mutect2, varscan2
- APBB1 | c.868C>T p.Q290* | Nonsense Mutation (SNP) | VAF 14/30 reads (47%) | catalogued as rs770812116, COSV100193734; called by muse, mutect2, varscan2
- APC | c.1585C>A p.L529I | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.257); catalogued as COSV99966177; called by muse, mutect2, varscan2
- API5 | c.1318A>G p.T440A | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.192); catalogued as COSV101124513; called by muse, mutect2, varscan2
- APLN | c.203G>A p.R68H | Missense Mutation (SNP) | VAF 50/103 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs758766922, COSV100278253; called by muse, mutect2, varscan2
- APOA5 | c.664G>A p.A222T | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.212); catalogued as rs772514533, COSV99911220; called by muse, mutect2, varscan2
- APOA5 | c.494del p.G165Afs*35 | Frame Shift Del (DEL) | VAF 4/40 reads (10%) | catalogued as CM119843; called by pindel, varscan2
- APP | c.917G>A p.R306H | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs202218688, COSV100695431; called by muse, mutect2, varscan2
- APPL1 | c.1115A>C p.N372T | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV99897492; called by muse, mutect2, varscan2
- AQP10 | c.188C>T p.S63F | Missense Mutation (SNP) | VAF 63/177 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.828); catalogued as COSV100270021; called by muse, mutect2, varscan2
- AQP12B | c.122C>T p.A41V | Missense Mutation (SNP) | VAF 38/100 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs959286311, COSV101315851; called by muse, mutect2, varscan2
- AQR | c.1948T>C p.Y650H | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV99333500; called by muse, mutect2, varscan2
- ARFIP2 | c.691G>A p.A231T | Missense Mutation (SNP) | VAF 38/70 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.044); catalogued as COSV99601454; called by muse, mutect2, varscan2
- ARG1 | c.450G>T p.K150N | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT tolerated (0.14); PolyPhen benign (0.074); catalogued as COSV99256027; called by muse, mutect2, varscan2
- ARHGAP10 | c.320G>T p.S107I | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.075); catalogued as COSV100331018; called by muse, mutect2, varscan2
- ARHGAP10 | c.1717-2A>C p.X573_splice | Splice Site (SNP) | VAF 19/34 reads (56%) | catalogued as COSV100331022; called by muse, mutect2, varscan2
- ARHGAP11A | c.2668G>T p.D890Y | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.556); catalogued as COSV100276714; called by muse, mutect2
- ARHGAP17 | c.1441C>T p.R481W | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs199829132, COSV99253057; called by muse, mutect2, varscan2
- ARHGAP18 | c.1820G>T p.R607M | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV100936052, COSV63763416; called by muse, mutect2, varscan2
- ARHGAP26 | c.2135C>T p.A712V | Missense Mutation (SNP) | VAF 35/82 reads (43%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as COSV99189628; called by muse, mutect2, varscan2
- ARHGAP32 | c.1084C>T p.R362W (on ENST00000310343 / NM_001378025.1; = p.R13W on NM_014715.4) | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs772669357, COSV100087231; called by muse, mutect2, varscan2
- ARHGAP32 | c.402G>T p.Q134H | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100087232; called by muse, mutect2, varscan2
- ARHGAP33 | c.154T>A p.F52I | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.964); catalogued as COSV99137724; called by muse, mutect2, varscan2
- ARHGAP33 | c.335G>A p.R112Q | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT tolerated, low confidence (0.23); PolyPhen probably damaging (0.91); catalogued as rs202132781, COSV50119830; called by muse, mutect2, varscan2
- ARHGAP36 | c.1337A>C p.E446A | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.681); catalogued as COSV99357398; called by muse, mutect2, varscan2
- ARHGAP39 | c.2657C>T p.S886F (on ENST00000276826 / NM_001308208.2; = p.S917F on NM_025251.2) | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99430543; called by muse, mutect2, varscan2
- ARHGEF1 | c.1430G>A p.R477H | Missense Mutation (SNP) | VAF 26/51 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.019); catalogued as rs782431103, COSV100528913; called by muse, mutect2, varscan2
- ARHGEF10L | c.2742G>T p.Q914H | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV99392274; called by muse, mutect2, varscan2
- ARHGEF15 | c.530C>T p.A177V | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as rs375713883; called by muse, mutect2, varscan2
- ARHGEF15 | c.1660C>A p.L554I | Missense Mutation (SNP) | VAF 28/50 reads (56%) | SIFT tolerated (0.59); PolyPhen probably damaging (0.995); catalogued as COSV100730012; called by muse, mutect2, varscan2
- ARHGEF15 | c.1901G>A p.R634H | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.811); catalogued as rs1487212983, COSV100730014; called by muse, mutect2, varscan2
- ARHGEF18 | c.2372G>A p.R791H (on ENST00000359920 / NM_001130955.2; = p.R687H on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.119); catalogued as rs1296443330, COSV100149194; called by muse, mutect2, varscan2
- ARHGEF19 | c.1937C>T p.A646V | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.824); catalogued as COSV99580159; called by muse, mutect2, varscan2
- ARHGEF28 | c.2049C>A p.N683K | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.186); catalogued as COSV99708448; called by muse, mutect2, varscan2
- ARHGEF37 | c.947C>A p.P316H | Missense Mutation (SNP) | VAF 36/89 reads (40%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.863); catalogued as COSV100381983; called by muse, mutect2, varscan2
- ARHGEF40 | c.202-1G>T p.X68_splice | Splice Site (SNP) | VAF 19/38 reads (50%) | catalogued as COSV100070147; called by muse, mutect2, varscan2
- ARHGEF40 | c.310G>T p.D104Y | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53884652; called by muse, mutect2, varscan2
- ARHGEF5 | c.2577G>T p.R859S | Missense Mutation (SNP) | VAF 34/160 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.146); catalogued as rs774516378, COSV99282667; called by muse, mutect2, varscan2
- ARHGEF6 | c.528G>T p.E176D | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as COSV99166396; called by muse, mutect2, varscan2
- ARID1A | c.4886C>T p.P1629L | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.278); catalogued as COSV100250730; called by muse, mutect2
- ARID2 | c.3782G>A p.R1261H | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs1199501070, COSV57599710; called by muse, mutect2, varscan2
- ARID3B | c.213A>T p.R71S | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.115); catalogued as COSV100654566; called by muse, mutect2, varscan2
- ARID5A | c.674C>A p.S225Y | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.459); catalogued as COSV100673543; called by muse, mutect2, varscan2
- ARL5A | c.65T>C p.V22A | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV99706565; called by muse, mutect2, varscan2
- ARMC2 | c.903G>T p.E301D | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.505); catalogued as COSV100933502; called by muse, mutect2, varscan2
- ARMC4 | c.2437C>A p.L813I | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as COSV100536487; called by muse, mutect2, varscan2
- ARMCX1 | c.710C>T p.S237L | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.595); catalogued as COSV100863166; called by muse, mutect2, varscan2
- ARMCX6 | c.88G>T p.G30* | Nonsense Mutation (SNP) | VAF 32/87 reads (37%) | catalogued as COSV100726223; called by muse, mutect2, varscan2
- ARNT2 | c.1201T>C p.Y401H | Missense Mutation (SNP) | VAF 27/54 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100308728; called by muse, mutect2, varscan2
- ARPP21 | c.1567C>T p.Q523* | Nonsense Mutation (SNP) | VAF 17/60 reads (28%) | catalogued as COSV51799978, COSV99491401; called by muse, mutect2, varscan2
- ARRDC1 | c.565G>A p.V189I | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs368553334; called by muse, mutect2, varscan2
- ARRDC3 | c.751C>T p.R251C | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.998); catalogued as rs1354978153, COSV54364489, COSV99475213; called by muse, mutect2, varscan2
- ARSI | c.1590G>T p.E530D | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV100155927; called by muse, mutect2
- ART3 | c.8C>T p.T3M | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.34); PolyPhen benign (0.097); catalogued as rs201551056; called by muse, mutect2
- ART3 | c.887A>T p.N296I | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.011); catalogued as COSV100587632; called by muse, mutect2, varscan2
- ART4 | c.755T>C p.L252P | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99966851; called by muse, mutect2, varscan2
- ARVCF | c.1256G>A p.R419Q | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.506); catalogued as rs1354725712, COSV99599043; called by muse, mutect2, varscan2
- ASAH1 | c.626G>T p.R209I | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV100025590; called by muse, mutect2, varscan2
- ASAP1 | c.336del p.D113Tfs*20 | Frame Shift Del (DEL) | VAF 6/33 reads (18%) | catalogued as COSV63055484; called by mutect2, pindel, varscan2
- ASB10 | c.727G>A p.A243T (on ENST00000420175 / NM_001142459.2; = p.A228T on NM_080871.4) | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.527); catalogued as COSV99318351; called by muse, mutect2, varscan2
- ASB17 | c.530dup p.N177Kfs*21 | Frame Shift Ins (INS) | VAF 16/40 reads (40%) | catalogued as rs749460467; called by mutect2, varscan2
- ASB17 | c.205G>T p.D69Y | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs770024127, COSV52412210; called by muse, mutect2, varscan2
- ASCC2 | c.2252G>A p.S751N | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs754488227, COSV100316104; called by muse, mutect2, varscan2
- ASCC3 | c.3271C>T p.R1091C | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755636587, COSV100225411; called by muse, mutect2, varscan2
- ASCC3 | c.2011T>C p.F671L | Missense Mutation (SNP) | VAF 29/56 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.04); catalogued as COSV100225413; called by muse, mutect2, varscan2
- ASH2L | c.612C>A p.Y204* | Nonsense Mutation (SNP) | VAF 7/16 reads (44%) | catalogued as COSV99166941; called by muse, mutect2, varscan2
- ASL | c.774G>T p.E258D | Missense Mutation (SNP) | VAF 34/66 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100508840; called by muse, mutect2, varscan2
- ASPH | c.254-1G>T p.X85_splice | Splice Site (SNP) | VAF 5/18 reads (28%) | catalogued as COSV100727452; called by muse, mutect2, varscan2
- ASPHD2 | c.785G>T p.G262V | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.796); catalogued as COSV99313192; called by muse, mutect2, varscan2
- ASTN1 | c.550C>T p.R184C | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as rs767625006, COSV56070602; called by muse, varscan2
- ASTN1 | c.535C>T p.R179C | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.065); catalogued as rs1369516870, COSV56064899, COSV56071491; called by muse, varscan2
- ASXL2 | c.1789T>G p.F597V | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.057); catalogued as COSV99710526; called by muse, mutect2, varscan2
- ATAD3A | c.465G>T p.Q155H | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.414); catalogued as COSV100186180; called by muse, mutect2, varscan2
- ATF7 | c.1099T>C p.W367R (on ENST00000548446 / NM_001366555.2; = p.W356R on NM_006856.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100129242; called by muse, mutect2, varscan2
- ATG2A | c.5338C>T p.R1780W | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1179284206, COSV65966282; called by muse, mutect2, varscan2
- ATG2A | c.2673C>A p.D891E | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.987); catalogued as COSV101034011; called by muse, mutect2, varscan2
- ATG2B | c.5611G>A p.A1871T | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99951982; called by muse, varscan2
- ATIC | c.1033G>T p.G345* | Nonsense Mutation (SNP) | VAF 12/27 reads (44%) | catalogued as COSV99377578; called by muse, mutect2, varscan2
- ATM | c.3331C>A p.L1111I | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.662); catalogued as COSV99588176; called by muse, varscan2
- ATOH8 | c.914G>A p.R305H | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.346); catalogued as rs372705499; called by muse, mutect2, varscan2
- ATP10B | c.2713C>T p.R905W | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV59163501; called by muse, mutect2, varscan2
- ATP10D | c.809G>A p.S270N | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.8); PolyPhen benign (0.014); catalogued as COSV99905334; called by muse, mutect2, varscan2
- ATP10D | c.1848del p.L617Cfs*41 | Frame Shift Del (DEL) | VAF 11/23 reads (48%) | catalogued as rs764067652, COSV56705401; called by mutect2, pindel, varscan2
- ATP11B | c.1099C>A p.L367I | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.302); catalogued as COSV100017626, COSV60026709; called by muse, mutect2, varscan2
- ATP12A | c.2231A>G p.D744G | Missense Mutation (SNP) | VAF 4/64 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV99517216; called by muse, mutect2
- ATP13A1 | c.2677C>T p.R893* | Nonsense Mutation (SNP) | VAF 13/25 reads (52%) | catalogued as rs151089864; called by muse, mutect2, varscan2
- ATP13A3 | c.1663C>A p.L555I | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.83); PolyPhen benign (0.015); catalogued as rs1226707973, COSV99756547; called by muse, mutect2, varscan2
- ATP2A2 | c.2519G>A p.G840D | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100428475; called by muse, mutect2, varscan2
- ATP2B1 | c.406+1G>A p.X136_splice | Splice Site (SNP) | VAF 10/25 reads (40%) | catalogued as COSV53807826; called by muse, mutect2, varscan2
- ATP2B2 | c.2323C>T p.R775W (on ENST00000352432; = p.R741W on NM_001683.5) | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59503450; called by muse, mutect2, varscan2
- ATP2B2 | c.1918C>T p.R640C (on ENST00000352432; = p.R606C on NM_001683.5) | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs748864193, COSV59510345; called by muse, mutect2, varscan2
- ATP2B3 | c.1367G>A p.R456H | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99683525; called by muse, mutect2, varscan2
- ATP5F1C | c.371C>A p.A124D | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT tolerated (0.39); PolyPhen benign (0.026); catalogued as COSV100184286; called by muse, mutect2, varscan2
- ATP5PO | c.199-1G>T p.X67_splice | Splice Site (SNP) | VAF 12/26 reads (46%) | catalogued as COSV99285502; called by muse, mutect2, varscan2
- ATP6AP1 | c.833A>G p.Y278C | Missense Mutation (SNP) | VAF 38/79 reads (48%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.907); catalogued as COSV100870661; called by muse, mutect2, varscan2
- ATP6AP1 | c.1000G>C p.V334L | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.676); catalogued as COSV100870662; called by muse, mutect2, varscan2
- ATP6AP1 | c.1394C>A p.S465Y | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); catalogued as COSV100870663, COSV63895822; called by muse, mutect2, varscan2
- ATP6V1A | c.91G>T p.A31S | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99849948; called by muse, mutect2, varscan2
- ATP6V1B1 | c.1032G>T p.Q344H | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99313893; called by muse, mutect2, varscan2
- ATP6V1D | c.239G>T p.S80I | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.61); catalogued as COSV99370766; called by muse, mutect2, varscan2
- ATP6V1H | c.597G>T p.Q199H | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.398); catalogued as COSV100778620; called by muse, mutect2, varscan2
- ATP7B | c.1811C>G p.A604G | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.68); catalogued as COSV99666183; called by muse, mutect2, varscan2
- ATP8A2 | c.652-1G>T p.X218_splice | Splice Site (SNP) | VAF 15/52 reads (29%) | catalogued as COSV99680760; called by muse, mutect2, varscan2
- ATP8A2 | c.1946C>T p.A649V | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.038); catalogued as COSV99680764; called by muse, mutect2, varscan2
- ATR | c.1033G>T p.A345S | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.001); catalogued as COSV100637836; called by muse, mutect2, varscan2
- ATRX | c.5771C>T p.S1924F | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV64878173; called by muse, mutect2, varscan2
- ATXN2L | c.2783C>T p.P928L | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs761504539, COSV57368563; called by muse, mutect2, varscan2
- ATXN7 | c.2285C>T p.T762M | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs368650687; called by muse, mutect2, varscan2
- AWAT2 | c.757G>A p.V253I | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (0.64); PolyPhen benign (0.014); catalogued as COSV99339578; called by muse, mutect2, varscan2
- AXIN1 | c.2287G>A p.E763K | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.72); PolyPhen benign (0.27); catalogued as rs568350522, COSV99249449; called by muse, mutect2, varscan2
- AXIN2 | c.1607C>T p.T536M | Missense Mutation (SNP) | VAF 37/87 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.489); catalogued as rs750084404, COSV61060942; called by muse, mutect2, varscan2
- AXIN2 | c.1349C>A p.P450H | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100196183; called by muse, mutect2, varscan2
- AZI2 | c.924G>T p.K308N | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.302); catalogued as COSV99843523; called by muse, mutect2, varscan2
- B4GALNT2 | c.1291C>A p.L431M | Missense Mutation (SNP) | VAF 35/94 reads (37%) | SIFT tolerated (0.22); PolyPhen benign (0.025); catalogued as COSV100302480; called by muse, mutect2, varscan2
- B4GALNT4 | c.2443C>T p.R815C | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0.258); catalogued as rs1320135417, COSV57321457; called by muse, mutect2, varscan2
- B4GALT1 | c.748G>T p.D250Y | Missense Mutation (SNP) | VAF 36/62 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101122967; called by muse, mutect2, varscan2
- B4GALT2 | c.281T>C p.L94P | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); catalogued as rs375270042; called by muse, mutect2, varscan2
- BACE2 | c.953C>T p.A318V | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs531921336, COSV57737876; called by muse, mutect2, varscan2
- BAK1 | c.250G>A p.D84N | Missense Mutation (SNP) | VAF 46/107 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.101); catalogued as rs892929984, COSV62349717; called by muse, mutect2, varscan2
- BAP1 | c.407A>G p.E136G | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99963598; called by muse, mutect2, varscan2
- BATF3 | c.146C>A p.A49D | Missense Mutation (SNP) | VAF 41/93 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99695941; called by muse, mutect2, varscan2
- BAZ2A | c.2168G>A p.R723Q | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT tolerated (0.6); PolyPhen benign (0.378); catalogued as COSV51631638; called by muse, mutect2, varscan2
- BBS12 | c.1291C>T p.R431W | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.636); catalogued as rs756955366, COSV100044859; called by muse, mutect2, varscan2
- BBS5 | c.482A>G p.Y161C | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.046); catalogued as COSV54753841; called by muse, mutect2, varscan2
- BCAN | c.1989G>T p.E663D | Missense Mutation (SNP) | VAF 63/159 reads (40%) | SIFT tolerated (0.55); PolyPhen benign (0.228); catalogued as COSV100227940; called by muse, mutect2, varscan2
- BCAR3 | c.2390A>G p.Q797R | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.742); catalogued as COSV53078001; called by muse, mutect2, varscan2
- BCAS3 | c.1526A>G p.N509S | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.931); catalogued as rs1342155653, COSV101175529; called by muse, mutect2, varscan2
- BCAT2 | c.1051C>A p.L351M | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as COSV100302334; called by muse, varscan2
- BCL11A | c.1841C>T p.A614V (on ENST00000335712 / NM_001365609.1; = p.A648V on NM_018014.4) | Missense Mutation (SNP) | VAF 15/25 reads (60%) | SIFT tolerated (0.34); PolyPhen benign (0.043); catalogued as rs987223589, COSV100185115; called by muse, mutect2, varscan2
- BCL11A | c.965C>T p.A322V (on ENST00000335712 / NM_001365609.1; = p.A356V on NM_018014.4) | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.461); catalogued as rs1330472358, COSV100185119; called by muse, mutect2, varscan2
- BCL11A | c.811C>T p.P271S (on ENST00000335712 / NM_001365609.1; = p.P305S on NM_018014.4) | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as COSV59638498; called by muse, mutect2, varscan2
- BCL11B | c.1460G>A p.R487H (on ENST00000357195 / NM_001282237.2; = p.R416H on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.835); catalogued as COSV100595291; called by muse, varscan2
- BCL11B | c.1420A>G p.M474V (on ENST00000357195 / NM_001282237.2; = p.M403V on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV61735140, COSV61735732; called by muse, varscan2
- BCORL1 | c.4406C>T p.T1469I | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT tolerated (0.55); PolyPhen benign (0.268); catalogued as COSV99498864, COSV99498896; called by muse, mutect2, varscan2
- BEND2 | c.664G>A p.A222T | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT tolerated (0.94); PolyPhen benign (0.003); catalogued as rs770529341, COSV66217323; called by muse, varscan2
- BEST4 | c.616G>A p.A206T | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT tolerated (0.33); PolyPhen benign (0.041); catalogued as COSV64734591; called by muse, mutect2, varscan2
- BHLHE22 | c.938G>A p.G313D | Missense Mutation (SNP) | VAF 9/12 reads (75%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV100417658; called by muse, mutect2, varscan2
- BHMT | c.1084C>T p.P362S | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as rs771334988, COSV99165384; called by muse, mutect2, varscan2
- BICC1 | c.266C>T p.A89V | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.978); catalogued as rs781532964, COSV100874764; called by muse, mutect2, varscan2
- BICD2 | c.2441C>T p.A814V | Missense Mutation (SNP) | VAF 83/169 reads (49%) | SIFT tolerated (0.37); PolyPhen benign (0.023); catalogued as rs765951746, COSV100794030; called by muse, mutect2, varscan2
- BICDL2 | c.1091C>T p.A364V | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV99560470; called by muse, mutect2, varscan2
- BICRAL | c.1139G>T p.S380I | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.549); catalogued as COSV100017921; called by muse, mutect2, varscan2
- BIN1 | c.736G>A p.A246T (on ENST00000316724 / NM_001320642.1; = p.A215T on NM_004305.4) | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.955); catalogued as rs974115762, COSV99387705; called by muse, mutect2, varscan2
- BIN3 | c.647T>A p.F216Y | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.903); catalogued as COSV99373889; called by muse, mutect2, varscan2
- BIRC6 | c.2470T>C p.Y824H | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV101427996; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.3507G>T p.Q1169H | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV100863659; called by muse, mutect2, varscan2
- BLM | c.477C>A p.D159E | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100757062; called by muse, mutect2, varscan2
- BLZF1 | c.962del p.K321Rfs*21 | Frame Shift Del (DEL) | VAF 6/22 reads (27%) | catalogued as rs1557849884; called by mutect2, pindel, varscan2
- BMP2 | c.595C>T p.Q199* | Nonsense Mutation (SNP) | VAF 14/27 reads (52%) | catalogued as COSV101122063; called by muse, mutect2
- BMP3 | c.970C>A p.L324I | Missense Mutation (SNP) | VAF 14/23 reads (61%) | SIFT tolerated (0.06); PolyPhen benign (0.162); catalogued as COSV99261473; called by muse, mutect2, varscan2
- BMP4 | c.1222C>T p.R408C | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs868400180, COSV99816823; called by muse, mutect2, varscan2
- BMP7 | c.855G>T p.E285D | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT tolerated (0.16); PolyPhen benign (0.033); catalogued as COSV101215678; called by muse, mutect2, varscan2
- BMPER | c.797T>C p.V266A | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.166); catalogued as COSV99779191; called by muse, mutect2, varscan2
- BMT2 | c.839C>A p.S280Y | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99774493; called by mutect2, varscan2
- BNC2 | c.610C>T p.H204Y | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.633); catalogued as COSV101032504; called by muse, mutect2, varscan2
- BNIPL | c.599A>C p.K200T | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.419); catalogued as COSV99764570; called by muse, mutect2, varscan2
- BOD1L1 | c.6871G>A p.A2291T | Missense Mutation (SNP) | VAF 34/68 reads (50%) | SIFT tolerated (0.22); PolyPhen benign (0.013); catalogued as rs767186765, COSV99238792; called by muse, mutect2, varscan2
- BOD1L1 | c.5258G>A p.R1753H | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs112328769, COSV99238510; called by muse, mutect2, varscan2
- BOLA3 | c.145G>T p.A49S | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as COSV99768115; called by muse, mutect2, varscan2
- BOLL | c.160del p.S54Pfs*6 | Frame Shift Del (DEL) | VAF 7/33 reads (21%) | catalogued as rs1428711101, COSV56578902; called by mutect2, pindel, varscan2
- BPGM | c.228G>T p.Q76H | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.025); catalogued as COSV100790183; called by muse, mutect2, varscan2
- BRAF | c.2321A>G p.N774S (on ENST00000288602 / NM_001374244.1; = p.N734S on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.954); catalogued as COSV99954797; called by muse, mutect2, varscan2
- BRAT1 | c.2189T>C p.I730T | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs143963658; called by muse, mutect2, varscan2
- BRAT1 | c.1183G>A p.V395M | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT tolerated (0.37); PolyPhen benign (0.02); catalogued as COSV100500389; called by muse, mutect2, varscan2
- BRCA2 | c.2710G>T p.G904* | Nonsense Mutation (SNP) | VAF 6/18 reads (33%) | catalogued as COSV101203874; called by muse, mutect2, varscan2
- BRD2 | c.1556G>A p.R519H | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.835); catalogued as rs982026329, COSV100875594; called by muse, mutect2, varscan2
- BRD4 | c.3775C>T p.R1259C | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1187497598, COSV99650130; called by muse, mutect2, varscan2
- BRF1 | c.1304G>A p.S435N | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as COSV100526975; called by muse, mutect2, varscan2
- BRIP1 | c.2629G>A p.A877T | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99369645; called by muse, mutect2, varscan2
- BRPF3 | c.2296C>T p.R766C | Missense Mutation (SNP) | VAF 40/81 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs551421725, COSV60208329; called by muse, mutect2, varscan2
- BRWD1 | c.5909C>T p.T1970I | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as COSV100313040; called by muse, mutect2, varscan2
- BRWD1 | c.2999G>T p.R1000M | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100313046; called by muse, mutect2, varscan2
- BTBD1 | c.1097T>C p.L366S | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as rs1186956494, COSV99915323; called by muse, mutect2, varscan2
- BTBD10 | c.693C>A p.Y231* | Nonsense Mutation (SNP) | VAF 7/18 reads (39%) | catalogued as COSV99533442; called by muse, mutect2, varscan2
- BTN3A1 | c.1140G>A p.W380* | Nonsense Mutation (SNP) | VAF 34/79 reads (43%) | catalogued as rs1291844965, COSV99175688; called by muse, mutect2, varscan2
- BTN3A2 | c.596T>C p.V199A | Missense Mutation (SNP) | VAF 27/55 reads (49%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV100709594; called by muse, mutect2, varscan2
- BTNL8 | c.1192G>A p.V398I | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs1224889478, COSV51456891; called by muse, mutect2, varscan2
- BTRC | c.521C>A p.P174H (on ENST00000370187 / NM_033637.4; = p.P138H on NM_003939.5) | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100926514; called by muse, mutect2, varscan2
- BUB1B | c.576G>T p.Q192H | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99806669; called by muse, mutect2, varscan2
- BUD13 | c.407C>T p.P136L | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.009); catalogued as COSV99496322; called by muse, mutect2, varscan2
- C11orf16 | c.1247A>G p.K416R | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.011); catalogued as COSV100214879; called by muse, mutect2, varscan2
- C12orf29 | c.668C>T p.A223V | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.44); PolyPhen benign (0.341); catalogued as rs1481741078, COSV100468118; called by muse, mutect2, varscan2
- C12orf50 | c.842A>G p.K281R | Missense Mutation (SNP) | VAF 29/50 reads (58%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV100072073; called by muse, mutect2, varscan2
- C14orf28 | c.880C>T p.P294S | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as COSV100290099; called by muse, mutect2, varscan2
- C14orf39 | c.791T>C p.V264A | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as rs756418466, COSV100407382; called by muse, mutect2, varscan2
- C15orf39 | c.1591A>G p.T531A | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.77); PolyPhen benign (0.295); catalogued as COSV100641239; called by muse, mutect2, varscan2
- C16orf71 | c.919G>A p.A307T | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as rs980152598, COSV54789527; called by muse, mutect2
- C16orf90 | c.71+1G>A p.X24_splice (on ENST00000399645 / NM_001353385.2; = p.V5I on NM_001080524.2) | Splice Site (SNP) | VAF 13/36 reads (36%) | catalogued as rs760186760, COSV101290954; called by muse, mutect2, varscan2
- C19orf44 | c.1592C>T p.T531I | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.236); catalogued as COSV99684991; called by muse, mutect2, varscan2
- C1QTNF2 | c.196G>A p.A66T (on ENST00000393975; = p.A21T on NM_031908.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.093); catalogued as rs374426172; called by muse, mutect2, varscan2
- C1QTNF3 | c.206G>T p.G69V | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV51468465, COSV99180691; called by muse, mutect2, varscan2
- C1orf198 | c.595C>T p.R199* | Nonsense Mutation (SNP) | VAF 25/66 reads (38%) | catalogued as rs564936718, COSV100793354; called by muse, mutect2, varscan2
- C1orf50 | c.485C>T p.P162L | Missense Mutation (SNP) | VAF 15/25 reads (60%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.784); catalogued as rs750596118, COSV65308230; called by muse, mutect2, varscan2
- C20orf194 | c.2333T>G p.M778R | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.044); catalogued as COSV99330434; called by muse, mutect2, varscan2
- C2CD2 | c.715G>A p.A239T | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.355); catalogued as COSV100298045; called by muse, mutect2, varscan2
- C2CD3 | c.304C>T p.Q102* | Nonsense Mutation (SNP) | VAF 19/56 reads (34%) | catalogued as COSV100076274; called by muse, mutect2, varscan2
- C2CD5 | c.470G>T p.R157I | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV100448569; called by muse, mutect2, varscan2
- C2CD6 | c.725G>T p.G242V | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99632273; called by muse, mutect2, varscan2
- C3 | c.1720C>T p.Q574* | Nonsense Mutation (SNP) | VAF 7/65 reads (11%) | catalogued as COSV99836262; called by muse, mutect2, varscan2
- C3 | c.899T>C p.V300A | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs756370451, COSV99836265; called by muse, mutect2, varscan2
- C6 | c.214G>T p.E72* | Nonsense Mutation (SNP) | VAF 6/23 reads (26%) | catalogued as rs909341673, COSV54716868, COSV99666749; called by muse, mutect2, varscan2
- C6orf15 | c.322G>T p.D108Y | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as COSV52540037, COSV99456721; called by muse, mutect2, varscan2
- C6orf201 | c.277G>A p.V93I | Missense Mutation (SNP) | VAF 20/35 reads (57%) | SIFT tolerated (0.22); PolyPhen benign (0.273); catalogued as COSV60987573; called by muse, mutect2, varscan2
- C6orf47 | c.745C>T p.L249F | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs372568469; called by muse, mutect2, varscan2
- C7orf25 | c.1091C>T p.T364M | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs772960316, COSV100623625; called by muse, mutect2, varscan2
- C7orf50 | c.75G>T p.E25D | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.026); catalogued as COSV100657406; called by muse, mutect2, varscan2
- C9orf135 | c.394C>T p.P132S | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as rs371568163; called by muse, mutect2, varscan2
- C9orf78 | c.432C>A p.D144E | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.988); catalogued as COSV100204124, COSV59612464; called by muse, varscan2
- CA11 | c.526C>T p.R176C | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs541610646, COSV50032716, COSV50033706; called by muse, mutect2, varscan2
- CA9 | c.917C>A p.T306N | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV100253083; called by muse, mutect2, varscan2
- CABIN1 | c.1142A>C p.K381T | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.494); catalogued as COSV99572871; called by muse, varscan2
- CABIN1 | c.2666T>C p.L889P | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99572872; called by muse, mutect2, varscan2
- CABIN1 | c.3777G>T p.E1259D | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); catalogued as COSV99572873; called by muse, mutect2, varscan2
- CACNA1B | c.2074C>A p.L692M | Missense Mutation (SNP) | VAF 46/95 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV53128888; called by muse, mutect2, varscan2
- CACNA1B | c.4718C>T p.A1573V | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53156842; called by muse, mutect2, varscan2
- CACNA1B | c.6632T>C p.I2211T | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV99495954; called by muse, mutect2, varscan2
- CACNA1G | c.430A>G p.K144E | Missense Mutation (SNP) | VAF 60/142 reads (42%) | SIFT tolerated (0.18); PolyPhen benign (0.374); catalogued as COSV61729592; called by muse, mutect2, varscan2
- CACNA1G | c.923C>A p.S308Y | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as COSV100661394, COSV61739927; called by muse, mutect2, varscan2
- CACNA1G | c.5960C>T p.T1987M | Missense Mutation (SNP) | VAF 36/71 reads (51%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.683); catalogued as rs201565895, COSV61724519; called by muse, mutect2, varscan2
- CACNA1S | c.1218A>C p.K406N | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.205); catalogued as COSV100754788; called by muse, mutect2, varscan2
- CACNA2D1 | c.2354C>A p.P785H (on ENST00000356253 / NM_001366867.1; = p.P773H on NM_000722.4) | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV100666254; called by muse, mutect2, varscan2
- CACNA2D3 | c.652A>G p.K218E | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.029); catalogued as rs766330689, COSV99871513; called by muse, mutect2, varscan2
- CACNA2D3 | c.2045C>T p.P682L | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.905); catalogued as COSV99871516; called by muse, mutect2, varscan2
- CACNA2D4 | c.1574G>A p.G525D | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1287980257, COSV99765277; called by muse, mutect2
- CACNG8 | c.128A>G p.Y43C | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99554900; called by muse, mutect2, varscan2
- CAD | c.4689C>A p.F1563L | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.132); catalogued as COSV99254643; called by muse, mutect2, varscan2
- CAD | c.5487G>T p.E1829D | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT tolerated (0.55); PolyPhen benign (0.011); catalogued as COSV99254646; called by muse, mutect2, varscan2
- CADM1 | c.524C>T p.T175M | Missense Mutation (SNP) | VAF 34/83 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs751706262, COSV100522301; called by muse, mutect2, varscan2
- CADM4 | c.484C>T p.R162C | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.94); catalogued as rs890982613, COSV55928349; called by muse, mutect2, varscan2
- CALCOCO2 | c.802C>A p.L268I | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.9); catalogued as COSV99363689; called by muse, mutect2, varscan2
- CALD1 | c.1215del p.E407Kfs*3 | Frame Shift Del (DEL) | VAF 9/22 reads (41%) | catalogued as rs1554470116; called by mutect2, pindel, varscan2
- CALM3 | c.319C>T p.R107C | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.015); catalogued as COSV52194735; called by muse, mutect2, varscan2
- CAMK1D | c.1120C>T p.P374S | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.067); catalogued as COSV66618078; called by muse, mutect2
- CAMK2G | c.1126G>T p.D376Y (on ENST00000423381 / NM_001367518.1; = p.D342Y on NM_001222.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.921); catalogued as COSV59481666; called by muse, mutect2, varscan2
- CAMSAP1 | c.1870G>A p.V624M | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs370692483, COSV100409680; called by muse, mutect2, varscan2
- CAMTA2 | c.3248G>A p.R1083Q | Missense Mutation (SNP) | VAF 41/113 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs1252243327, COSV99236293; called by muse, mutect2, varscan2
- CAP1 | c.994-1G>T p.X332_splice | Splice Site (SNP) | VAF 13/18 reads (72%) | catalogued as COSV100471993; called by muse, mutect2, varscan2
- CAPN10 | c.1940A>G p.D647G | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.783); catalogued as rs747336055, COSV99550045; called by muse, mutect2, varscan2
- CAPN11 | c.146C>T p.A49V | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.353); catalogued as COSV101291859; called by muse, mutect2, varscan2
- CAPN12 | c.1898A>C p.D633A | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV99399889; called by muse, mutect2, varscan2
- CAPN13 | c.1937G>A p.R646H | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs766688300, COSV54428545; called by muse, mutect2, varscan2
- CAPN15 | c.1922C>T p.A641V | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1225063940, COSV99562092; called by muse, mutect2, varscan2
- CAPN2 | c.1246C>T p.R416* | Nonsense Mutation (SNP) | VAF 18/40 reads (45%) | catalogued as rs558508236, COSV99688687; called by muse, mutect2, varscan2
- CAPN3 | c.231C>A p.D77E | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100532667; called by muse, mutect2, varscan2
- CAPN9 | c.725C>A p.S242Y | Missense Mutation (SNP) | VAF 33/87 reads (38%) | SIFT tolerated (1); PolyPhen probably damaging (0.975); catalogued as COSV99680097; called by muse, mutect2
- CAPS2 | c.1018C>T p.L340F | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.397); catalogued as rs377661352; called by muse, varscan2
- CARD10 | c.683G>A p.R228H | Missense Mutation (SNP) | VAF 37/63 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs780666568, COSV52657550; called by muse, mutect2, varscan2
- CARD16 | c.358G>A p.A120T | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.677); catalogued as rs112423474, COSV65212664, COSV65213151; called by muse, mutect2, varscan2
- CARD6 | c.2273G>T p.G758V | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.603); catalogued as COSV99620474; called by muse, mutect2, varscan2
- CARMIL1 | c.1864G>A p.A622T | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100277265; called by mutect2, varscan2
- CARS1 | c.347G>A p.R116Q | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.53); PolyPhen benign (0.298); catalogued as rs145015718; called by muse, mutect2, varscan2
- CASKIN1 | c.1475A>G p.N492S | Missense Mutation (SNP) | VAF 38/134 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.931); catalogued as rs867235687, COSV100623884; called by muse, varscan2
- CASQ2 | c.639G>T p.E213D | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.175); catalogued as COSV99797188; called by muse, mutect2, varscan2
- CASS4 | c.2304G>T p.Q768H | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.228); catalogued as COSV100824583; called by muse, mutect2, varscan2
- CASTOR1 | c.719T>C p.V240A | Missense Mutation (SNP) | VAF 28/59 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.579); catalogued as COSV100355625; called by muse, mutect2, varscan2
- CASZ1 | c.2579C>T p.A860V | Missense Mutation (SNP) | VAF 46/128 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.327); catalogued as COSV100680936; called by muse, mutect2, varscan2
- CATSPER2 | c.778G>A p.V260I | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT tolerated (0.57); PolyPhen benign (0.057); catalogued as COSV100390620; called by muse, mutect2, varscan2
- CBLC | c.968G>A p.G323D | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV99541884; called by muse, mutect2, varscan2
- CBLIF | c.868C>T p.P290S | Missense Mutation (SNP) | VAF 37/81 reads (46%) | SIFT tolerated (0.42); PolyPhen benign (0.012); catalogued as COSV57238116, COSV99950797; called by muse, mutect2, varscan2
- CBLN4 | c.452C>T p.A151V | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV50352509, COSV50353669; called by muse, mutect2, varscan2
- CBWD1 | c.890T>C p.L297P | Missense Mutation (SNP) | VAF 46/133 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100070717; called by muse, mutect2, varscan2
- CCDC103 | c.149T>G p.I50S | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99493120; called by muse, mutect2, varscan2
- CCDC110 | c.2348A>G p.N783S | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as COSV100293758; called by muse, mutect2, varscan2
- CCDC138 | c.1288T>C p.Y430H | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV99718912; called by muse, mutect2, varscan2
- CCDC141 | c.2756A>C p.K919T | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99836434; called by muse, mutect2, varscan2
- CCDC142 | c.412C>T p.P138S | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.007); catalogued as rs1193984953, COSV99282004; called by muse, mutect2, varscan2
- CCDC18 | c.2610G>T p.K870N (on ENST00000343253 / NM_001306076.1; = p.K871N on NM_206886.4) | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV100159345; called by muse, mutect2, varscan2
- CCDC180 | c.500del p.L167* | Frame Shift Del (DEL) | VAF 11/34 reads (32%) | catalogued as rs577900246; called by mutect2, pindel, varscan2
- CCDC190 | c.899T>G p.L300R | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.943); catalogued as COSV100905810; called by muse, mutect2
- CCDC25 | c.619T>G p.F207V | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100738212; called by muse, mutect2, varscan2
- CCDC25 | c.465G>T p.E155D | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.492); catalogued as COSV100738214; called by muse, mutect2, varscan2
- CCDC3 | c.710A>G p.H237R | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0); catalogued as COSV101121639; called by muse, mutect2, varscan2
- CCDC30 | c.1984C>T p.R662* (on ENST00000340612; = p.R619* on NM_001080850.3) | Nonsense Mutation (SNP) | VAF 38/87 reads (44%) | catalogued as rs944852189, COSV100501175; called by muse, mutect2, varscan2
- CCDC47 | c.785C>T p.A262V | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.687); catalogued as COSV99854060; called by muse, mutect2, varscan2
- CCDC65 | c.4C>T p.P2S | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as COSV99907969; called by muse, mutect2
- CCDC73 | c.977T>C p.V326A | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.65); PolyPhen benign (0.264); catalogued as COSV100066792; called by muse, mutect2, varscan2
- CCDC74A | c.490G>A p.A164T | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV99723654; called by muse, mutect2, varscan2
- CCDC78 | c.1100G>A p.G367D | Missense Mutation (SNP) | VAF 40/79 reads (51%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV99557276; called by muse, mutect2, varscan2
- CCDC8 | c.1160C>A p.A387D | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.989); catalogued as COSV100281943; called by muse, mutect2, varscan2
- CCDC80 | c.316C>T p.Q106* | Nonsense Mutation (SNP) | VAF 28/59 reads (47%) | catalogued as COSV99244456; called by muse, mutect2, varscan2
- CCDC82 | c.1486G>T p.E496* | Nonsense Mutation (SNP) | VAF 25/52 reads (48%) | catalogued as COSV99567140; called by muse, mutect2, varscan2
- CCDC85A | c.1319C>T p.A440V | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.11); catalogued as COSV101339410; called by muse, mutect2, varscan2
- CCDC88B | c.2427G>T p.Q809H | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.135); catalogued as COSV57267354; called by muse, varscan2
- CCER1 | c.778G>A p.A260T | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as COSV100726966; called by muse, mutect2, varscan2
- CCL20 | c.96C>A p.C32* | Nonsense Mutation (SNP) | VAF 4/10 reads (40%) | catalogued as COSV100721792; called by muse, mutect2
- CCL26 | c.92A>G p.K31R | Missense Mutation (SNP) | VAF 27/44 reads (61%) | SIFT tolerated (0.18); PolyPhen benign (0.115); catalogued as COSV99139126; called by muse, mutect2, varscan2
- CCN3 | c.697C>T p.R233C | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.761); catalogued as COSV99422806; called by muse, mutect2, varscan2
- CCND1 | c.551C>T p.T184I | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); catalogued as COSV99919333; called by muse, mutect2, varscan2
- CCNT1 | c.1679G>T p.S560I | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.271); catalogued as COSV99980560; called by muse, mutect2, varscan2
- CCNT1 | c.63T>A p.N21K | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.03); catalogued as COSV99980561; called by muse, mutect2, varscan2
- CCR5 | c.386C>A p.A129D | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99433217; called by muse, mutect2, varscan2
- CCR6 | c.10-1G>T p.X4_splice | Splice Site (SNP) | VAF 24/60 reads (40%) | catalogued as COSV100551016; called by muse, mutect2, varscan2
- CCSER2 | c.887C>A p.A296D | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV99825637; called by muse, mutect2, varscan2
- CCT7 | c.980G>T p.G327V | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99240592; called by muse, mutect2, varscan2
- CCT7 | c.1571G>A p.R524H | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.607); catalogued as rs779069312, COSV54589719; called by muse, mutect2, varscan2
- CCT8L2 | c.316G>A p.A106T | Missense Mutation (SNP) | VAF 36/83 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV63463037; called by muse, mutect2, varscan2
- CCZ1B | c.1091A>G p.N364S | Missense Mutation (SNP) | VAF 36/144 reads (25%) | SIFT tolerated (0.39); PolyPhen benign (0.312); catalogued as COSV100367797; called by muse, mutect2
- CD109 | c.2468G>T p.R823M | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.027); catalogued as COSV54656046; called by muse, mutect2, varscan2
- CD22 | c.941A>G p.D314G | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.675); catalogued as COSV99322984; called by muse, mutect2, varscan2
- CD300LB | c.6G>A p.W2* | Nonsense Mutation (SNP) | VAF 15/31 reads (48%) | catalogued as COSV100075351, COSV100075466; called by muse, mutect2, varscan2
- CD33 | c.38-1G>T p.X13_splice | Splice Site (SNP) | VAF 25/58 reads (43%) | catalogued as COSV99220179; called by muse, mutect2, varscan2
- CD36 | c.290T>C p.F97S | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.197); catalogued as COSV99987290; called by muse, mutect2, varscan2
- CD4 | c.46C>A p.L16M | Missense Mutation (SNP) | VAF 100/242 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV99163704; called by muse, mutect2
- CD4 | c.1081C>A p.L361M | Missense Mutation (SNP) | VAF 37/89 reads (42%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.932); catalogued as COSV99163705; called by muse, mutect2, varscan2
- CD44 | c.217G>A p.G73R | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99556400; called by muse, mutect2, varscan2
- CD47 | c.533C>A p.A178D | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.2); PolyPhen benign (0.012); catalogued as COSV100790103; called by muse, mutect2, varscan2
- CD59 | c.187A>G p.K63E | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as rs1203520607, COSV100681158; called by muse, mutect2, varscan2
- CD63 | c.299C>T p.A100V | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.047); catalogued as COSV99141732; called by muse, mutect2, varscan2
- CD93 | c.812G>A p.C271Y | Missense Mutation (SNP) | VAF 38/67 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99849004; called by muse, mutect2, varscan2
- CDAN1 | c.2174G>A p.R725Q | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs962870388, COSV100661202; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CDC16 | c.1733C>T p.T578M | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.098); catalogued as rs773269949, COSV52959127; called by mutect2, varscan2
- CDC42BPA | c.3554C>A p.T1185N (on ENST00000334218 / NM_001366019.2; = p.T1172N on NM_003607.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV100504161; called by muse, mutect2, varscan2
- CDC42BPG | c.4293del p.F1431Lfs*16 | Frame Shift Del (DEL) | VAF 10/44 reads (23%) | catalogued as rs570535506; called by pindel, varscan2
- CDC42BPG | c.920G>T p.S307I | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.543); catalogued as COSV100712004, COSV61346337; called by muse, mutect2, varscan2
- CDC42BPG | c.238G>T p.G80* | Nonsense Mutation (SNP) | VAF 16/30 reads (53%) | catalogued as COSV100712005, COSV61345585; called by muse, mutect2, varscan2
- CDC42SE1 | c.194C>T p.S65F | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.431); catalogued as COSV100603344; called by muse, mutect2, varscan2
- CDC5L | c.2024G>T p.S675I | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious (0.02); PolyPhen benign (0.202); catalogued as COSV101014904; called by muse, mutect2, varscan2
- CDC73 | c.1351G>A p.A451T | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT tolerated (0.17); PolyPhen benign (0.088); catalogued as rs1553291414, COSV100813741; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CDH11 | c.1174G>T p.V392F | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51769357, COSV51777466; called by muse, mutect2, varscan2
- CDH17 | c.847C>T p.P283S | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99217104; called by muse, mutect2, varscan2
- CDH19 | c.1583C>T p.T528I | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100051169; called by muse, mutect2
- CDH20 | c.1737C>A p.S579R | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.113); catalogued as COSV99404708; called by muse, mutect2, varscan2
- CDK11A | c.110del p.N37Ifs*17 | Frame Shift Del (DEL) | VAF 27/92 reads (29%) | catalogued as rs767014805; called by mutect2, pindel, varscan2
- CDK16 | c.1007C>T p.S336F | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99331540; called by muse, mutect2, varscan2
- CDK18 | c.1381C>T p.R461C (on ENST00000506784 / NM_212503.3; = p.R431C on NM_002596.4) | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as rs751066133, COSV100773962; called by mutect2, varscan2
- CDK20 | c.827G>A p.R276H (on ENST00000325303 / NM_001039803.3; = p.R255H on NM_012119.4) | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369652911; called by muse, mutect2, varscan2
- CDK5 | c.711G>T p.K237N | Missense Mutation (SNP) | VAF 28/99 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.804); catalogued as rs757027718, COSV99876737; called by muse, mutect2, varscan2
- CDK5RAP2 | c.2290G>A p.A764T | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs746203438, COSV62573211, COSV62573947; called by mutect2, varscan2
- CDK5RAP2 | c.1385A>C p.K462T | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.273); catalogued as COSV62577719; called by muse, mutect2, varscan2
- CDK7 | c.496A>G p.N166D | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.41); PolyPhen benign (0.021); catalogued as COSV99841585; called by muse, mutect2, varscan2
- CDKL4 | c.357A>G p.I119M | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.153); catalogued as COSV66509711; called by muse, mutect2, varscan2
- CDKL5 | c.964A>G p.T322A | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.369); catalogued as COSV101184135; called by muse, mutect2, varscan2
- CDKL5 | c.1525G>A p.A509T | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as COSV101184137; called by muse, mutect2, varscan2
- CDKN2A | c.357G>T p.E119D | Missense Mutation (SNP) | VAF 24/40 reads (60%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.868); catalogued as COSV100445869; called by muse, mutect2, varscan2
- CDKN2AIP | c.1248G>T p.Q416H | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.158); catalogued as COSV100187566; called by muse, mutect2, varscan2
- CDO1 | c.383A>T p.N128I | Missense Mutation (SNP) | VAF 36/84 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99164757; called by muse, varscan2
- CDRT1 | c.1504G>T p.D502Y | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100599797; called by muse, mutect2, varscan2
- CDT1 | c.1541G>A p.R514H | Missense Mutation (SNP) | VAF 50/117 reads (43%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs754064981, COSV56348582, COSV99967119; called by muse, mutect2, varscan2
- CEACAM16 | c.1000G>A p.V334I | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.874); catalogued as rs761104359, COSV69186567; called by muse, mutect2, varscan2
- CECR2 | c.725C>T p.T242I (on ENST00000342247 / NM_001290047.2; = p.T79I on NM_001290046.1) | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.598); catalogued as COSV99377316; called by muse, mutect2, varscan2
- CELF3 | c.829C>A p.L277M | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated (0.22); PolyPhen benign (0.22); catalogued as COSV99310124; called by muse, varscan2
- CELF3 | c.773-1G>T p.X258_splice | Splice Site (SNP) | VAF 22/46 reads (48%) | catalogued as COSV99310127; called by muse, varscan2
- CELF4 | c.578-1G>A p.X193_splice | Splice Site (SNP) | VAF 5/10 reads (50%) | catalogued as COSV100611310; called by muse, mutect2, varscan2
- CELSR2 | c.470G>T p.R157M | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT tolerated (0.21); PolyPhen benign (0.133); catalogued as COSV99603322; called by muse, mutect2, varscan2
- CELSR2 | c.638C>T p.A213V | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); catalogued as rs763935264, COSV54781254; called by muse, mutect2, varscan2
- CELSR2 | c.4965G>T p.Q1655H | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as COSV99603330; called by muse, mutect2, varscan2
- CEMP1 | c.223G>A p.V75I | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.621); catalogued as rs757728422, COSV99565699; called by muse, varscan2
- CEMP1 | c.145G>A p.A49T | Missense Mutation (SNP) | VAF 23/42 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.122); catalogued as rs368671860; called by muse, varscan2
- CENPE | c.793T>G p.L265V | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99477335; called by muse, mutect2, varscan2
- CENPI | c.33G>T p.Q11H | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.003); catalogued as COSV99515125; called by muse, varscan2
- CENPI | c.113A>G p.N38S | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV99515127; called by muse, varscan2
- CENPL | c.587T>A p.I196N | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as COSV100616275; called by muse, mutect2, varscan2
- CENPT | c.184C>T p.R62C | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs892367026, COSV99534919; called by muse, mutect2, varscan2
- CENPU | c.710T>G p.I237S | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.697); catalogued as COSV99859801; called by muse, mutect2, varscan2
- CENPV | c.668C>T p.T223I | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.031); catalogued as COSV100233443, COSV55332954; called by muse, mutect2, varscan2
- CEP104 | c.2571+2T>C p.X857_splice | Splice Site (SNP) | VAF 13/68 reads (19%) | catalogued as COSV100986582, COSV65520020; called by muse, varscan2
- CEP126 | c.3226C>T p.L1076F | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99680773; called by muse, mutect2, varscan2
- CEP128 | c.2594G>A p.R865H | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.958); catalogued as rs1166133031, COSV99824038; called by muse, mutect2, varscan2
- CEP131 | c.1466G>A p.S489N | Missense Mutation (SNP) | VAF 33/89 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.16); catalogued as rs182537101, COSV53955828, COSV99487971; called by muse, mutect2, varscan2
- CEP162 | c.3302T>C p.I1101T | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.439); catalogued as COSV100002506; called by muse, mutect2, varscan2
- CEP164 | c.1107G>T p.K369N | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.775); catalogued as COSV54041265, COSV99632763; called by muse, mutect2, varscan2
- CEP250 | c.445C>T p.R149W | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs373038487; called by muse, mutect2, varscan2
- CEP290 | c.635dup p.N212Kfs*3 | Frame Shift Ins (INS) | VAF 10/22 reads (45%) | catalogued as rs769091629; called by mutect2, varscan2
- CEP350 | c.9051C>A p.N3017K | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.074); catalogued as rs868213400, COSV100854402; called by muse, mutect2, varscan2
- CEP43 | c.557G>A p.S186N | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.058); catalogued as rs781301988, COSV100835577; called by muse, mutect2, varscan2
- CEP72 | c.866G>A p.R289H | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs143569794; called by muse, mutect2
- CEP76 | c.464C>A p.A155D | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV100042648; called by muse, mutect2, varscan2
- CEP76 | c.295del p.T99Lfs*90 | Frame Shift Del (DEL) | VAF 30/40 reads (75%) | catalogued as rs747064410; called by mutect2, varscan2
- CEP85L | c.2378G>A p.R793H | Missense Mutation (SNP) | VAF 33/72 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as rs768605927, COSV100874123; called by muse, mutect2, varscan2
- CERS6 | c.778T>G p.C260G | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as COSV99986739; called by muse, mutect2, varscan2
- CERT1 | c.1468G>A p.V490M (on ENST00000405807 / NM_001130105.1; = p.V362M on NM_005713.3) | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.034); catalogued as COSV99783009; called by muse, mutect2, varscan2
- CES1 | c.665C>T p.A222V | Missense Mutation (SNP) | VAF 28/114 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as rs1351062972, COSV62086174; called by muse, mutect2, varscan2
- CES2 | c.1528C>A p.L510M | Missense Mutation (SNP) | VAF 35/81 reads (43%) | SIFT tolerated (0.45); PolyPhen benign (0.038); catalogued as COSV100399120; called by muse, mutect2, varscan2
- CETN1 | c.176C>T p.A59V | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.904); catalogued as COSV59121768; called by muse, mutect2, varscan2
- CETN2 | c.383G>A p.R128H | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.104); catalogued as COSV100938629; called by muse, mutect2, varscan2
- CFAP251 | c.1105G>T p.V369F | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as COSV99995843; called by muse, mutect2, varscan2
- CFAP46 | c.7645C>T p.R2549* | Nonsense Mutation (SNP) | VAF 21/41 reads (51%) | catalogued as rs973200087, COSV99584215; called by muse, mutect2, varscan2
- CFAP46 | c.6778C>T p.R2260C | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.458); catalogued as rs562594842, COSV99584221; called by muse, mutect2, varscan2
- CFAP47 | c.155C>T p.T52M | Missense Mutation (SNP) | VAF 38/102 reads (37%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.961); catalogued as COSV52887759; called by muse, mutect2, varscan2
- CFAP47 | c.2118G>T p.R706S | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.079); catalogued as COSV99934622; called by muse, mutect2, varscan2
- CFAP54 | c.5791G>T p.A1931S | Missense Mutation (SNP) | VAF 11/16 reads (69%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.635); catalogued as COSV100733032; called by muse, mutect2, varscan2
- CFAP61 | c.1193A>C p.K398T | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV99843840; called by muse, mutect2, varscan2
- CFAP65 | c.3520A>G p.N1174D | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.858); catalogued as COSV100444811; called by muse, mutect2, varscan2
- CFAP65 | c.1896dup p.M633Hfs*35 | Frame Shift Ins (INS) | VAF 14/29 reads (48%) | catalogued as rs762731091; called by mutect2, varscan2
- CFAP69 | c.1373-1G>T p.X458_splice | Splice Site (SNP) | VAF 20/57 reads (35%) | catalogued as COSV100289916, COSV100290347; called by muse, mutect2, varscan2
- CFHR4 | c.1292G>A p.G431E (on ENST00000367416 / NM_001201551.2; = p.G185E on NM_006684.5) | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.578); catalogued as COSV52229902; called by muse, mutect2, varscan2
- CFHR4 | c.1537C>T p.H513Y (on ENST00000367416 / NM_001201551.2; = p.H267Y on NM_006684.5) | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs776058842, COSV99259849; called by muse, mutect2, varscan2
- CGB2 | c.122G>A p.C41Y | Missense Mutation (SNP) | VAF 20/129 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1296245349, COSV100031565; called by muse, mutect2, varscan2
- CGN | c.127G>T p.A43S | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.69); PolyPhen possibly damaging (0.492); catalogued as COSV99642041; called by muse, mutect2, varscan2
- CH25H | c.474G>T p.K158N | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.894); catalogued as COSV100897332; called by muse, mutect2, varscan2
- CHAC1 | c.610G>A p.A204T | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.971); catalogued as rs758148587, COSV101471065, COSV71436018; called by muse, varscan2
- CHD1 | c.2872A>G p.T958A | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs1272831845, COSV99399226; called by muse, mutect2, varscan2
- CHD2 | c.956G>A p.S319N | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.018); catalogued as COSV100560583; called by muse, mutect2, varscan2
- CHD2 | c.1205G>T p.S402I | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.768); catalogued as COSV100560584; called by muse, mutect2, varscan2
- CHD2 | c.1397G>A p.R466Q | Missense Mutation (SNP) | VAF 27/48 reads (56%) | SIFT deleterious (0.01); PolyPhen benign (0.201); catalogued as COSV59122507; called by muse, mutect2, varscan2
- CHD4 | c.1894C>T p.R632W (on ENST00000357008 / NM_001363606.2; = p.R645W on NM_001273.5) | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100537569, COSV58907433; called by muse, mutect2, varscan2
- CHD4 | c.686C>T p.A229V | Missense Mutation (SNP) | VAF 35/109 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV100537570; called by muse, mutect2, varscan2
- CHD7 | c.1161G>T p.Q387H | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.979); catalogued as COSV101418074; called by muse, mutect2, varscan2
- CHD7 | c.7397T>C p.I2466T | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT tolerated (0.49); PolyPhen benign (0.007); catalogued as COSV101418075; called by muse, mutect2
- CHD8 | c.1355T>G p.L452W (on ENST00000646647 / NM_001170629.2; = p.L173W on NM_020920.4) | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.963); catalogued as COSV101303071; called by muse, mutect2, varscan2
- CHERP | c.2350C>T p.R784W | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.353); catalogued as COSV52222055; called by muse, mutect2, varscan2
- CHGA | c.71C>T p.P24L | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as COSV53664170, COSV99381016; called by muse, varscan2
- CHMP1A | c.431A>G p.E144G | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT tolerated (0.13); PolyPhen benign (0.061); catalogued as COSV99498298; called by muse, mutect2, varscan2
- CHPF | c.1948G>A p.A650T | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.55); PolyPhen benign (0.085); catalogued as COSV60537523; called by muse, mutect2, varscan2
- CHPF2 | c.1066T>C p.W356R | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99222944; called by mutect2, varscan2
- CHPT1 | c.328C>A p.L110M | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99977643; called by muse, mutect2, varscan2
- CHRDL1 | c.488C>A p.S163Y (on ENST00000372045; = p.S169Y on NM_145234.4) | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.377); catalogued as COSV99487831; called by muse, mutect2, varscan2
- CHRDL1 | c.182G>A p.C61Y (on ENST00000372045; = p.C67Y on NM_145234.4) | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99487834; called by muse, mutect2, varscan2
- CHRM2 | c.872C>A p.A291D | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated (0.58); PolyPhen benign (0.361); catalogued as COSV100280914; called by muse, mutect2, varscan2
- CHRM4 | c.536C>T p.T179M | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs759941649, COSV63126375; called by muse, mutect2, varscan2
- CHRM5 | c.634C>A p.L212I | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.107); catalogued as COSV67246951; called by muse, mutect2, varscan2
- CHRNA9 | c.363C>T p.N121= | Splice Region (SNP) | VAF 7/36 reads (19%) | catalogued as COSV100038862; called by muse, mutect2
- CHRNB2 | c.1082T>C p.L361P | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.26); PolyPhen benign (0.033); catalogued as rs1226774233, COSV100872562; called by muse, mutect2
- CHRND | c.1457C>A p.A486D | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.821); catalogued as COSV99285602; called by muse, mutect2, varscan2
- CHST5 | c.1045C>T p.R349C | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.717); catalogued as rs774087462, COSV100291794; called by muse, mutect2, varscan2
- CHST6 | c.562C>T p.L188F | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); catalogued as COSV100178314; called by muse, mutect2, varscan2
- CHSY3 | c.1195C>T p.P399S | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); catalogued as rs1395629600, COSV100518723; called by muse, mutect2, varscan2
- CHSY3 | c.1580G>C p.R527P | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as COSV100518724, COSV59289746; called by muse, mutect2, varscan2
- CHTF18 | c.817G>A p.G273S | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as rs371218247; called by muse, mutect2, varscan2
- CHTF18 | c.917A>C p.K306T | Missense Mutation (SNP) | VAF 41/117 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs763295767, COSV99135650; called by muse, mutect2, varscan2
- CILP | c.544G>A p.V182M | Missense Mutation (SNP) | VAF 29/60 reads (48%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV99972999; called by muse, mutect2, varscan2
- CISH | c.754C>T p.R252* (on ENST00000348721 / NM_145071.4; = p.R269* on NM_013324.6) | Nonsense Mutation (SNP) | VAF 23/61 reads (38%) | catalogued as rs770662400, COSV100811741; called by muse, mutect2, varscan2
- CKAP5 | c.4374G>T p.E1458D | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.115); catalogued as COSV100370558; called by muse, mutect2, varscan2
- CKB | c.248A>G p.E83G | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.185); catalogued as COSV100818912; called by muse, mutect2
- CKMT1A | c.868C>T p.L290F | Missense Mutation (SNP) | VAF 28/85 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV101376808; called by muse, mutect2, varscan2
- CKMT2 | c.560A>T p.E187V | Missense Mutation (SNP) | VAF 61/133 reads (46%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.716); catalogued as COSV99562309; called by muse, mutect2, varscan2
- CLCN2 | c.1222C>T p.R408C | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); catalogued as COSV55599877; called by muse, mutect2, varscan2
- CLCN2 | c.830G>A p.R277Q | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1027524389, COSV55602526; called by muse, mutect2, varscan2
- CLCN2 | c.211C>T p.R71* | Nonsense Mutation (SNP) | VAF 17/33 reads (52%) | catalogued as rs1055985062, COSV99658346; called by muse, mutect2, varscan2
- CLCN3 | c.155C>T p.A52V | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.27); PolyPhen benign (0.011); catalogued as COSV100641624; called by muse, mutect2, varscan2
- CLCN3 | c.1364T>C p.L455P | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100641625; called by muse, mutect2, varscan2
- CLCN5 | c.2095G>A p.V699I | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.622); catalogued as rs201962580, COSV56585581; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CLCN6 | c.2486C>T p.T829M | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs763754640, COSV100411690; called by muse, mutect2, varscan2
- CLDN1 | c.627C>A p.D209E | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.07); catalogued as COSV99790532; called by muse, mutect2, varscan2
- CLDN14 | c.317G>A p.R106H | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT tolerated (0.22); PolyPhen benign (0.027); catalogued as rs747254086, COSV59777692; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CLDN15 | c.650G>A p.S217N | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs1305160943, COSV100385195; called by muse, mutect2, varscan2
- CLDN17 | c.460C>T p.H154Y | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.38); PolyPhen benign (0.407); catalogued as COSV99729067; called by muse, mutect2, varscan2
- CLDN8 | c.81G>A p.M27I | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.779); catalogued as COSV99729729; called by muse, mutect2, varscan2
- CLEC10A | c.769G>A p.A257T (on ENST00000254868 / NM_182906.4; = p.A233T on NM_006344.4) | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.038); catalogued as COSV99644605; called by muse, mutect2, varscan2
- CLIC2 | c.212C>T p.P71L | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782270791, COSV58935841; called by muse, mutect2, varscan2
- CLIC6 | c.1469C>A p.S490Y (on ENST00000360731 / NM_001317009.2; = p.S472Y on NM_053277.3) | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62447100; called by muse, mutect2, varscan2
- CLIP3 | c.1640C>A p.S547Y | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.962); catalogued as COSV99430923; called by muse, mutect2, varscan2
- CLIP4 | c.10G>T p.E4* | Nonsense Mutation (SNP) | VAF 27/57 reads (47%) | catalogued as COSV100191603; called by muse, mutect2, varscan2
- CLMN | c.885+2T>C p.X295_splice | Splice Site (SNP) | VAF 7/17 reads (41%) | catalogued as COSV100112183; called by muse, mutect2, varscan2
- CLMN | c.609-1G>A p.X203_splice | Splice Site (SNP) | VAF 15/36 reads (42%) | catalogued as COSV100112184; called by muse, mutect2, varscan2
- CLMP | c.938G>A p.R313H | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as COSV71649476; called by muse, mutect2, varscan2
- CLPTM1L | c.953T>C p.M318T | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.159); catalogued as COSV100306920; called by muse, mutect2, varscan2
- CLRN1 | c.314C>A p.S105Y (on ENST00000327047 / NM_174878.3; = p.S29Y on NM_052995.2) | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.832); catalogued as COSV99902373; called by muse, mutect2, varscan2
- CLSPN | c.968G>A p.R323Q | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs750708437, COSV52047717, COSV52052369; called by muse, mutect2, varscan2
- CLSTN3 | c.1050G>T p.Q350H | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV99866670; called by muse, mutect2, varscan2
- CLTC | c.3751C>T p.R1251* | Nonsense Mutation (SNP) | VAF 21/48 reads (44%) | catalogued as COSV99291893; called by muse, mutect2, varscan2
- CLTRN | c.593C>T p.S198F | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV100982191, COSV66712517; called by muse, mutect2, varscan2
- CMAS | c.540G>T p.W180C | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99982592; called by muse, mutect2, varscan2
- CMTR1 | c.248G>A p.R83H | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); catalogued as rs1168631606, COSV65090669; called by muse, mutect2, varscan2
- CMYA5 | c.2427G>T p.Q809H | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.027); catalogued as COSV101483945; called by muse, mutect2
- CNDP1 | c.1090G>A p.V364I | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.559); catalogued as COSV100722227; called by muse, mutect2, varscan2
- CNGA3 | c.526G>A p.A176T | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated (0.56); PolyPhen benign (0.01); catalogued as rs1256677667, COSV55622065, COSV55623656; called by muse, mutect2, varscan2
- CNGA3 | c.1469T>C p.L490P | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99736324; called by muse, mutect2, varscan2
- CNGB1 | c.3169C>A p.L1057M | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99202179; called by muse, mutect2, varscan2
- CNGB1 | c.2169G>A p.T723= | Splice Region (SNP) | VAF 23/50 reads (46%) | catalogued as rs775308719, COSV99202197; called by muse, mutect2, varscan2
- CNKSR2 | c.1193A>T p.E398V | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99667821; called by muse, mutect2, varscan2
- CNN3 | c.500A>G p.Q167R | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.531); catalogued as COSV100930920; called by muse, mutect2, varscan2
- CNNM1 | c.1977C>A p.H659Q | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.165); catalogued as COSV100763792; called by muse, mutect2, varscan2
- CNOT1 | c.6646A>G p.N2216D | Missense Mutation (SNP) | VAF 56/120 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99799560; called by muse, mutect2, varscan2
- CNOT11 | c.1391T>G p.I464S | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as COSV99179233; called by muse, varscan2
- CNOT6 | c.490+3_490+6del p.X164_splice | Splice Site (DEL) | VAF 6/22 reads (27%) | catalogued as rs1355093495; called by pindel, varscan2
- CNOT6L | c.1631C>A p.P544H (on ENST00000504123 / NM_001286790.2; = p.P539H on NM_144571.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/107 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); catalogued as COSV99361547; called by muse, mutect2, varscan2
- CNOT9 | c.388C>T p.R130C | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99813638; called by muse, mutect2, varscan2
- CNPY4 | c.736G>T p.E246* | Nonsense Mutation (SNP) | VAF 17/39 reads (44%) | catalogued as COSV53542381, COSV99498789; called by muse, mutect2, varscan2
- CNTFR | c.49G>A p.A17T | Missense Mutation (SNP) | VAF 53/152 reads (35%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs933732260, COSV63634400; called by muse, mutect2, varscan2
- CNTLN | c.3922del p.M1308* | Frame Shift Del (DEL) | VAF 16/41 reads (39%) | catalogued as rs761011518, COSV99078405; called by mutect2, pindel, varscan2
- CNTN1 | c.1221G>T p.K407N | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.856); catalogued as COSV100751116; called by muse, mutect2, varscan2
- CNTN1 | c.1722G>T p.Q574H | Missense Mutation (SNP) | VAF 17/30 reads (57%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.819); catalogued as COSV100751117; called by muse, mutect2, varscan2
- CNTN1 | c.2575G>A p.V859I | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.043); catalogued as COSV100751119; called by muse, varscan2
- CNTN1 | c.2605G>A p.E869K | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.868); catalogued as rs200286741; called by muse, varscan2
- CNTN5 | c.2515G>A p.E839K | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs765175673, COSV99674432; called by muse, mutect2, varscan2
- CNTN6 | c.626G>A p.G209D | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs1261241221, COSV100610350; called by muse, mutect2, varscan2
- CNTNAP2 | c.1633G>A p.A545T | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs747922335, COSV62158230, COSV99080851; called by muse, mutect2, varscan2
- CNTNAP2 | c.3197A>G p.Y1066C | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV100664068, COSV62167993; called by muse, mutect2, varscan2
- CNTNAP3 | c.2981C>T p.P994L | Missense Mutation (SNP) | VAF 33/87 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.534); catalogued as rs1468285999, COSV99904386; called by muse, mutect2, varscan2
- COA5 | c.223T>G p.*75Gext*18 | Nonstop Mutation (SNP) | VAF 26/56 reads (46%) | catalogued as rs757396278, COSV100158629; called by muse, mutect2, varscan2
- COBL | c.2051C>G p.A684G | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.112); catalogued as COSV99471745; called by muse, mutect2, varscan2
- COBLL1 | c.2834del p.L945Cfs*12 (on ENST00000392717; = p.L907Cfs*12 on NM_014900.5) | Frame Shift Del (DEL) | VAF 9/12 reads (75%) | catalogued as rs374805044; called by mutect2, varscan2
- COBLL1 | c.1174A>G p.N392D (on ENST00000392717; = p.N354D on NM_014900.5) | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.699); catalogued as rs764604402, COSV99527531; called by mutect2, varscan2
- COCH | c.1673G>T p.G558V (on ENST00000216361 / NM_001347720.1; = p.G493V on NM_004086.3) | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99363468; called by muse, mutect2, varscan2
- COG4 | c.808G>A p.V270I | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.22); PolyPhen benign (0.009); catalogued as COSV100091460; called by muse, mutect2, varscan2
- COL10A1 | c.764C>T p.P255L | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as COSV99684006; called by muse, mutect2, varscan2
- COL11A2 | c.2089G>A p.G697S (on ENST00000341947 / NM_080680.3; = p.G590S on NM_080679.2) | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100553595; called by muse, mutect2, varscan2
- COL11A2 | c.747G>T p.Q249H | Missense Mutation (SNP) | VAF 76/186 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.333); catalogued as COSV100553597; called by muse, mutect2, varscan2
- COL12A1 | c.5840C>A p.P1947H | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.935); catalogued as COSV59389311, COSV59403904; called by muse, mutect2, varscan2
- COL12A1 | c.3458A>G p.Y1153C | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59408711; called by muse, mutect2, varscan2
- COL14A1 | c.3128T>C p.I1043T | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs903514326, COSV99918438; called by muse, mutect2, varscan2
- COL15A1 | c.710C>A p.P237H | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV100897523; called by muse, mutect2, varscan2
- COL15A1 | c.3017C>T p.A1006V | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.014); catalogued as COSV100897524; called by muse, mutect2, varscan2
- COL16A1 | c.971G>A p.R324Q | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs375999793; called by muse, mutect2, varscan2
- COL17A1 | c.2395A>G p.K799E | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); catalogued as COSV100793092; called by muse, mutect2, varscan2
- COL19A1 | c.2947G>T p.G983C | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749516621, COSV100505657; called by muse, mutect2, varscan2
4,984 further variants in this file (3,499 protein-altering or splice-affecting, 1,354 silent, 131 other) are not listed here.
